Somatic mutation profile of tumor specimen TCGA-JX-A3Q0-01A (aliquot TCGA-JX-A3Q0-01A-11D-A21Q-09) from TCGA case TCGA-JX-A3Q0, project TCGA-CESC (Cervical Squamous Cell Carcinoma and Endocervical Adenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Cervix uteri; FIGO stage: Stage III; Tumor grade: G2; Age at diagnosis: 63.8 years (23,313 days).
Specimen TCGA-JX-A3Q0-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 195a77b6-bdd3-44de-8451-5f960248729d.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-JX-A3Q0-10A (Blood Derived Normal), aliquot TCGA-JX-A3Q0-10A-01D-A21Q-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/29c75aea-29bd-4a8e-b852-7956650d5281

The open-access MAF lists 810 somatic variants for this specimen: 569 protein-altering or splice-affecting, 227 silent, 14 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 498, Silent 227, Nonsense Mutation 58, Intron 10, Splice Site 4, Splice Region 4, In Frame Del 2, Frame Shift Ins 2, 5'UTR 2, RNA 1, Frame Shift Del 1, 5'Flank 1.

Variants (750 of 810; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ASPM | c.2967G>A p.W989* | Nonsense Mutation (SNP) | VAF 18/58 reads (31%) | catalogued as rs199422152, CM091957, COSV54128085; ClinVar: pathogenic; called by muse, mutect2, varscan2
- FBXW7 | c.1513C>G p.R505G (on ENST00000281708 / NM_001349798.2; = p.R425G on NM_018315.5) | Missense Mutation (SNP) | VAF 14/44 reads (32%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs149680468, COSV55890969, COSV55891274, COSV55898451; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- IRAK4 | c.34C>T p.R12C | Missense Mutation (SNP) | VAF 13/30 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs377584435, CM078314; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- NFE2L2 | c.85G>T p.D29Y | Missense Mutation (SNP) | VAF 12/31 reads (39%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1057519920, COSV67960002, COSV67960389, COSV67960852; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- PIK3CA | c.1633G>A p.E545K | Missense Mutation (SNP) | VAF 17/72 reads (24%) | hotspot (GDC flag); SIFT deleterious (0.02); PolyPhen probably damaging (0.909); catalogued as rs104886003, CM126692, COSV55873239, COSV55878227; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- AAAS | c.593C>T p.S198F | Missense Mutation (SNP) | VAF 12/31 reads (39%) | SIFT tolerated (0.48); PolyPhen benign (0.121); catalogued as COSV52932656; called by muse, mutect2, varscan2
- ABCA13 | c.7666G>A p.D2556N | Missense Mutation (SNP) | VAF 9/19 reads (47%) | SIFT deleterious (0.04); PolyPhen benign (0.017); catalogued as COSV71285761; called by muse, mutect2, varscan2
- ABTB1 | c.941C>T p.S314L (on ENST00000232744 / NM_172027.3; = p.S172L on NM_032548.3) | Missense Mutation (SNP) | VAF 8/31 reads (26%) | SIFT tolerated (0.2); PolyPhen benign (0.001); catalogued as rs141326451, COSV99229604; called by muse, mutect2, varscan2
- ACAN | c.5135G>A p.G1712E | Missense Mutation (SNP) | VAF 17/54 reads (31%) | SIFT tolerated (0.17); PolyPhen probably damaging (1); catalogued as rs760776040, COSV61358864; called by muse, mutect2, varscan2
- ACAN | c.7288G>C p.D2430H (on ENST00000560601 / NM_001369268.1; = p.D2354H on NM_001135.3) | Missense Mutation (SNP) | VAF 11/29 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.506); catalogued as COSV61358791, COSV61358872; called by muse, mutect2, varscan2
- ACAP3 | c.247G>A p.D83N | Missense Mutation (SNP) | VAF 11/55 reads (20%) | SIFT tolerated (0.12); PolyPhen benign (0.197); catalogued as rs1398008806, COSV61221971; called by muse, mutect2, varscan2
- ACCSL | c.1328-1G>C p.X443_splice | Splice Site (SNP) | VAF 20/46 reads (43%) | catalogued as COSV66580876; called by muse, mutect2, varscan2
- ACTR5 | c.491G>A p.G164E | Missense Mutation (SNP) | VAF 43/127 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV54760391; called by muse, mutect2, varscan2
- ACVR1B | c.1004A>G p.D335G | Missense Mutation (SNP) | VAF 20/47 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV57776249; called by muse, mutect2, varscan2
- ADAM23 | c.803G>T p.R268I | Missense Mutation (SNP) | VAF 15/34 reads (44%) | SIFT tolerated (0.17); PolyPhen benign (0); catalogued as COSV52212087; called by muse, mutect2, varscan2
- ADAMTS10 | c.121A>T p.I41F | Missense Mutation (SNP) | VAF 15/37 reads (41%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.888); catalogued as COSV54353625; called by muse, mutect2, varscan2
- ADAMTS12 | c.4768A>G p.K1590E | Missense Mutation (SNP) | VAF 25/70 reads (36%) | SIFT tolerated (0.63); PolyPhen benign (0.011); catalogued as COSV61260312; called by muse, mutect2, varscan2
- ADCY9 | c.2757G>A p.M919I | Missense Mutation (SNP) | VAF 7/70 reads (10%) | SIFT deleterious (0.01); PolyPhen benign (0.057); catalogued as COSV99569440; called by muse, mutect2, varscan2
- ADGRE5 | c.1435G>A p.D479N (on ENST00000242786 / NM_078481.4; = p.D386N on NM_001784.5) | Missense Mutation (SNP) | VAF 10/30 reads (33%) | SIFT tolerated (0.51); PolyPhen benign (0); catalogued as COSV54409695; called by muse, mutect2
- ADGRG4 | c.1667C>T p.T556I | Missense Mutation (SNP) | VAF 7/105 reads (7%) | SIFT deleterious (0); PolyPhen benign (0.033); catalogued as rs1188546301, COSV99794475; called by muse, mutect2
- ADGRG5 | c.1124C>G p.S375C | Missense Mutation (SNP) | VAF 16/45 reads (36%) | SIFT tolerated (0.08); PolyPhen benign (0.273); catalogued as COSV61082988; called by muse, mutect2, varscan2
- AHNAK | c.9283G>A p.D3095N | Missense Mutation (SNP) | VAF 40/135 reads (30%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.994); catalogued as COSV57210108; called by muse, mutect2, varscan2
- AHNAK2 | c.15814G>A p.D5272N | Missense Mutation (SNP) | VAF 13/35 reads (37%) | SIFT tolerated (0.44); PolyPhen benign (0.023); catalogued as COSV60912623; called by muse, mutect2, varscan2
- AKNA | c.1525G>C p.E509Q | Missense Mutation (SNP) | VAF 11/33 reads (33%) | SIFT tolerated (0.11); PolyPhen benign (0.007); catalogued as COSV56312112; called by muse, mutect2, varscan2
- AL121899.2 | c.1816G>A p.E606K | Missense Mutation (SNP) | VAF 23/87 reads (26%) | SIFT deleterious (0.05); PolyPhen benign (0.031); catalogued as COSV67350257; called by muse, mutect2, varscan2
- ALDH1L2 | c.1036G>A p.E346K | Missense Mutation (SNP) | VAF 22/72 reads (31%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.143); catalogued as COSV51554817; called by muse, mutect2, varscan2
- ALG13 | c.278G>A p.G93E | Missense Mutation (SNP) | VAF 10/38 reads (26%) | SIFT deleterious, low confidence (0.04); PolyPhen possibly damaging (0.783); catalogued as rs759598704, COSV52637633; called by muse, mutect2, varscan2
- AMD1 | c.999G>C p.Q333H | Missense Mutation (SNP) | VAF 4/23 reads (17%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.007); catalogued as COSV64387213; called by muse, mutect2
- ANKHD1-EIF4EBP3 | c.3244G>C p.E1082Q | Missense Mutation (SNP) | VAF 15/29 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV51844682; called by muse, mutect2, varscan2
- APRT | c.496G>A p.E166K | Missense Mutation (SNP) | VAF 17/64 reads (27%) | SIFT tolerated (0.19); PolyPhen benign (0.049); catalogued as COSV51936597; called by muse, mutect2, varscan2
- ARFGEF1 | c.3532G>A p.G1178R | Missense Mutation (SNP) | VAF 19/41 reads (46%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.771); catalogued as COSV51606193; called by muse, mutect2, varscan2
- ARHGEF10L | c.2334C>G p.F778L | Missense Mutation (SNP) | VAF 10/52 reads (19%) | SIFT tolerated (0.67); PolyPhen possibly damaging (0.81); catalogued as COSV51428031, COSV51430695; called by muse, mutect2, varscan2
- ARHGEF11 | c.1393G>C p.E465Q | Missense Mutation (SNP) | VAF 10/90 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.757); catalogued as COSV63810705, COSV63811543; called by muse, mutect2, varscan2
- ARHGEF15 | c.1329C>G p.F443L | Missense Mutation (SNP) | VAF 6/19 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV62724817, COSV62724859; called by muse, mutect2, varscan2
- ARID2 | c.1250C>T p.S417L | Missense Mutation (SNP) | VAF 25/51 reads (49%) | SIFT tolerated (0.54); PolyPhen possibly damaging (0.549); catalogued as COSV57601188; called by muse, mutect2, varscan2
- ARMC2 | c.1037G>C p.R346T | Missense Mutation (SNP) | VAF 19/57 reads (33%) | SIFT deleterious (0.02); PolyPhen benign (0.026); catalogued as COSV64550712; called by muse, mutect2, varscan2
- ARMC4 | c.1651C>G p.L551V | Missense Mutation (SNP) | VAF 23/52 reads (44%) | SIFT tolerated (0.06); PolyPhen benign (0.145); catalogued as COSV59461147; called by muse, mutect2, varscan2
- ARNT | c.1792G>T p.E598* | Nonsense Mutation (SNP) | VAF 9/42 reads (21%) | catalogued as COSV62230313; called by muse, mutect2, varscan2
- ARNT | c.745C>G p.Q249E | Missense Mutation (SNP) | VAF 16/82 reads (20%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.872); catalogued as COSV62230316; called by muse, varscan2
- ASAP1 | c.2680C>T p.L894F | Missense Mutation (SNP) | VAF 8/10 reads (80%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.994); catalogued as COSV63047060; called by muse, mutect2, varscan2
- ASPHD1 | c.590C>T p.S197L | Missense Mutation (SNP) | VAF 29/115 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.549); catalogued as COSV58098628; called by muse, mutect2, varscan2
- ASTN1 | c.1097C>T p.S366L | Missense Mutation (SNP) | VAF 22/83 reads (27%) | SIFT tolerated, low confidence (0.54); PolyPhen benign (0.366); catalogued as COSV99920582, COSV99921489; called by muse, mutect2, varscan2
- ASXL2 | c.2224G>A p.E742K | Missense Mutation (SNP) | VAF 8/55 reads (15%) | SIFT tolerated, low confidence (0.06); PolyPhen possibly damaging (0.76); catalogued as COSV55453029, COSV55456777; called by muse, mutect2, varscan2
- ASXL2 | c.1456G>A p.E486K | Missense Mutation (SNP) | VAF 5/63 reads (8%) | SIFT tolerated (0.2); PolyPhen benign (0.039); catalogued as rs1246090124, COSV55454714, COSV55456647, COSV99710306; called by muse, mutect2
- ATF7IP2 | c.1384G>T p.E462* | Nonsense Mutation (SNP) | VAF 4/16 reads (25%) | catalogued as COSV61093087; called by muse, mutect2
- ATG13 | c.1258G>C p.E420Q (on ENST00000359513 / NM_001346321.1; = p.E383Q on NM_014741.4 and 9 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 11/51 reads (22%) | SIFT tolerated (0.54); PolyPhen benign (0.037); catalogued as COSV56318603; called by muse, mutect2, varscan2
- ATG4C | c.1319C>T p.S440L | Missense Mutation (SNP) | VAF 17/52 reads (33%) | SIFT tolerated (0.72); PolyPhen benign (0.001); catalogued as COSV58605076; called by muse, mutect2, varscan2
- ATP13A5 | c.376G>C p.E126Q | Missense Mutation (SNP) | VAF 21/75 reads (28%) | SIFT tolerated (0.46); PolyPhen benign (0.271); catalogued as COSV60868087; called by muse, mutect2, varscan2
- ATP2C1 | c.1910C>T p.S637L | Missense Mutation (SNP) | VAF 15/68 reads (22%) | SIFT tolerated (0.79); PolyPhen benign (0.001); catalogued as COSV100146311; called by muse, mutect2, varscan2
- ATP6V1B2 | c.135C>T p.L45= | Splice Region (SNP) | VAF 33/70 reads (47%) | catalogued as COSV99369254; called by muse, mutect2, varscan2
- ATR | c.7255G>A p.E2419K | Missense Mutation (SNP) | VAF 9/34 reads (26%) | SIFT tolerated (0.28); PolyPhen benign (0.184); catalogued as COSV63383777; called by muse, mutect2
- ATR | c.6930G>C p.K2310N | Missense Mutation (SNP) | VAF 11/60 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.945); catalogued as COSV63385544; called by muse, mutect2, varscan2
- ATRNL1 | c.2584C>T p.P862S | Missense Mutation (SNP) | VAF 17/41 reads (41%) | SIFT tolerated (0.68); PolyPhen probably damaging (0.996); catalogued as COSV58082318; called by muse, mutect2, varscan2
- ATRX | c.2232G>A p.M744I | Missense Mutation (SNP) | VAF 16/59 reads (27%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.057); catalogued as COSV64874590; called by muse, mutect2, varscan2
- AUP1 | c.40G>C p.D14H | Missense Mutation (SNP) | VAF 15/35 reads (43%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.971); catalogued as COSV51206920; called by muse, mutect2, varscan2
- AUTS2 | c.2674G>C p.E892Q | Missense Mutation (SNP) | VAF 17/35 reads (49%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.542); catalogued as rs1232698720, COSV61393924; called by muse, mutect2, varscan2
- AXIN2 | c.1196G>A p.R399Q | Missense Mutation (SNP) | VAF 17/39 reads (44%) | SIFT tolerated (0.28); PolyPhen benign (0.003); catalogued as rs765865516, COSV61056803; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- BAG5 | c.934G>A p.G312S | Missense Mutation (SNP) | VAF 9/35 reads (26%) | SIFT tolerated (0.22); PolyPhen benign (0.015); catalogued as COSV99914636; called by mutect2, varscan2
- BAIAP3 | c.1121C>T p.S374L | Missense Mutation (SNP) | VAF 27/95 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as rs746749524, COSV60979199; called by muse, varscan2
- BCOR | c.8C>T p.S3L | Missense Mutation (SNP) | VAF 8/47 reads (17%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.989); catalogued as COSV60704890, COSV60705153; called by muse, mutect2, varscan2
- BEX5 | c.295C>G p.P99A | Missense Mutation (SNP) | VAF 17/44 reads (39%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.826); catalogued as COSV61328530, COSV61328537; called by muse, mutect2, varscan2
- BIRC6 | c.5609G>A p.R1870K | Missense Mutation (SNP) | VAF 11/17 reads (65%) | SIFT tolerated (0.08); PolyPhen benign (0.023); catalogued as rs766401012, COSV70197804; called by muse, mutect2, varscan2
- BMPER | c.1136C>T p.T379I | Missense Mutation (SNP) | VAF 8/52 reads (15%) | SIFT tolerated (0.28); PolyPhen benign (0.406); catalogued as COSV51815617; called by muse, mutect2, varscan2
- BRWD1 | c.2642G>C p.R881T | Missense Mutation (SNP) | VAF 17/28 reads (61%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.468); catalogued as COSV60894563; called by muse, mutect2, varscan2
- BRWD3 | c.2326-1G>A p.X776_splice | Splice Site (SNP) | VAF 16/61 reads (26%) | catalogued as COSV64746609; called by muse, mutect2, varscan2
- BSN | c.2011C>T p.Q671* | Nonsense Mutation (SNP) | VAF 12/39 reads (31%) | catalogued as COSV56515859; called by muse, mutect2, varscan2
- BTK | c.1021C>G p.Q341E | Missense Mutation (SNP) | VAF 8/73 reads (11%) | SIFT tolerated (1); PolyPhen benign (0.192); catalogued as COSV58118713; called by muse, mutect2, varscan2
- C12orf43 | c.82G>A p.E28K | Missense Mutation (SNP) | VAF 20/42 reads (48%) | SIFT deleterious (0.03); PolyPhen benign (0.061); catalogued as rs1176572996, COSV56566313, COSV56566816; called by muse, mutect2, varscan2
- C16orf91 | c.95C>T p.S32F | Missense Mutation (SNP) | VAF 14/50 reads (28%) | SIFT deleterious (0.01); PolyPhen benign (0.192); catalogued as rs780209328, COSV59949913; called by muse, mutect2, varscan2
- C19orf44 | c.1444G>A p.E482K | Missense Mutation (SNP) | VAF 11/58 reads (19%) | SIFT tolerated (0.12); PolyPhen benign (0.424); catalogued as COSV99684919; called by muse, mutect2, varscan2
- C1orf112 | c.13C>T p.H5Y | Missense Mutation (SNP) | VAF 17/59 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as rs150100828; called by muse, mutect2, varscan2
- C1orf116 | c.1396C>T p.L466F | Missense Mutation (SNP) | VAF 9/33 reads (27%) | SIFT deleterious (0.01); PolyPhen benign (0.28); catalogued as COSV63943938; called by muse, mutect2
- C1orf116 | c.337G>T p.E113* | Nonsense Mutation (SNP) | VAF 30/86 reads (35%) | catalogued as COSV63943864, COSV63943943; called by muse, mutect2, varscan2
- C2CD2L | c.1613C>T p.S538F | Missense Mutation (SNP) | VAF 15/44 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100371087; called by muse, mutect2, varscan2
- C2CD5 | c.484C>A p.H162N | Missense Mutation (SNP) | VAF 11/40 reads (28%) | SIFT deleterious (0.02); PolyPhen benign (0.142); catalogued as COSV100448495; called by muse, mutect2, varscan2
- C6 | c.263G>A p.G88E | Missense Mutation (SNP) | VAF 14/29 reads (48%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.647); catalogued as COSV54708450; called by muse, mutect2, varscan2
- CACHD1 | c.3049C>T p.H1017Y | Missense Mutation (SNP) | VAF 4/37 reads (11%) | SIFT tolerated (0.1); PolyPhen benign (0.003); catalogued as COSV51551612; called by muse, mutect2, varscan2
- CAMKMT | c.719G>A p.R240K | Missense Mutation (SNP) | VAF 24/58 reads (41%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as COSV65924900; called by muse, mutect2, varscan2
- CAPN9 | c.613G>A p.E205K | Missense Mutation (SNP) | VAF 16/52 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55232603; called by muse, mutect2, varscan2
- CARD10 | c.2149G>A p.E717K | Missense Mutation (SNP) | VAF 14/44 reads (32%) | SIFT tolerated (0.15); PolyPhen benign (0.072); catalogued as COSV52655640; called by muse, mutect2, varscan2
- CARD6 | c.2450G>A p.R817K | Missense Mutation (SNP) | VAF 8/21 reads (38%) | SIFT tolerated (0.06); PolyPhen benign (0.017); catalogued as COSV54565545; called by muse, mutect2, varscan2
- CASP8 | c.1303C>T p.R435* (on ENST00000432109 / NM_033355.3; = p.R452* on NM_001228.4) | Nonsense Mutation (SNP) | VAF 14/40 reads (35%) | catalogued as rs1368296717, COSV51844657; called by muse, mutect2
- CCDC120 | c.776G>A p.R259Q | Missense Mutation (SNP) | VAF 26/89 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.946); catalogued as rs781838355, COSV64515037; called by muse, mutect2, varscan2
- CCDC122 | c.7G>A p.D3N | Missense Mutation (SNP) | VAF 20/60 reads (33%) | SIFT tolerated, low confidence (0.22); PolyPhen benign (0.025); catalogued as COSV55709134; called by muse, mutect2, varscan2
- CCDC28B | c.250G>A p.E84K | Missense Mutation (SNP) | VAF 9/37 reads (24%) | SIFT deleterious (0); PolyPhen benign (0.003); catalogued as rs766218771, COSV52208416; called by muse, mutect2, varscan2
- CCDC78 | c.274C>T p.R92W | Missense Mutation (SNP) | VAF 6/29 reads (21%) | SIFT tolerated (0.22); PolyPhen benign (0.001); catalogued as rs769448022, COSV52400804; called by muse, mutect2, varscan2
- CDH1 | c.2282G>A p.G761E | Missense Mutation (SNP) | VAF 32/95 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs876659664, COSV55730619; ClinVar: uncertain significance; called by muse, varscan2
- CDKN2A | c.92T>G p.L31R | Missense Mutation (SNP) | VAF 10/22 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV58692210, COSV58726989; called by muse, varscan2
- CDRT4 | c.212C>T p.S71F | Missense Mutation (SNP) | VAF 17/47 reads (36%) | SIFT tolerated (0.13); PolyPhen benign (0.029); catalogued as rs753693958, COSV56465108; called by muse, mutect2, varscan2
- CENPF | c.6865C>G p.L2289V | Missense Mutation (SNP) | VAF 9/27 reads (33%) | SIFT deleterious (0.01); PolyPhen benign (0.266); catalogued as COSV65274019; called by muse, mutect2, varscan2
- CEP104 | c.1354G>T p.E452* | Nonsense Mutation (SNP) | VAF 14/72 reads (19%) | catalogued as COSV100986565; called by muse, varscan2
- CEP128 | c.3028C>T p.Q1010* | Nonsense Mutation (SNP) | VAF 26/63 reads (41%) | catalogued as COSV55373298; called by muse, mutect2, varscan2
- CEP128 | c.1334C>T p.S445L | Missense Mutation (SNP) | VAF 15/38 reads (39%) | SIFT tolerated (0.07); PolyPhen benign (0.001); catalogued as COSV99823772; called by muse, mutect2, varscan2
- CEP170 | c.4168C>T p.Q1390* | Nonsense Mutation (SNP) | VAF 26/87 reads (30%) | catalogued as COSV60508034; called by muse, mutect2, varscan2
- CFAP57 | c.728C>T p.S243L | Missense Mutation (SNP) | VAF 4/19 reads (21%) | SIFT tolerated (0.41); PolyPhen benign (0); catalogued as COSV100993836; called by muse, mutect2, varscan2
- CFP | c.617C>T p.S206L | Missense Mutation (SNP) | VAF 34/129 reads (26%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.99); catalogued as CM001763, COSV55950021; called by muse, mutect2, varscan2
- CGN | c.3079-1G>A p.X1027_splice | Splice Site (SNP) | VAF 8/40 reads (20%) | catalogued as COSV54969220; called by muse, mutect2, varscan2
- CGN | c.3583G>A p.E1195K | Missense Mutation (SNP) | VAF 19/58 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1193599745, COSV54969233; called by muse, mutect2, varscan2
- CHD3 | c.5800G>A p.A1934T (on ENST00000330494 / NM_001005273.3; = p.A1900T on NM_005852.4) | Missense Mutation (SNP) | VAF 21/50 reads (42%) | SIFT tolerated, low confidence (0.34); PolyPhen benign (0.001); catalogued as COSV57873999; called by muse, mutect2, varscan2
- CHD5 | c.883G>A p.E295K | Missense Mutation (SNP) | VAF 8/33 reads (24%) | SIFT tolerated (0.36); PolyPhen benign (0.003); catalogued as COSV52412092; called by muse, mutect2, varscan2
- CHD6 | c.7258C>T p.L2420F | Missense Mutation (SNP) | VAF 7/24 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV64689621; called by muse, mutect2, varscan2
- CLASRP | c.1318C>T p.R440W | Missense Mutation (SNP) | VAF 9/15 reads (60%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.916); catalogued as rs1229193420, COSV55515544; called by muse, mutect2, varscan2
- CLCN5 | c.1840G>A p.E614K | Missense Mutation (SNP) | VAF 17/89 reads (19%) | SIFT tolerated (0.32); PolyPhen benign (0.015); catalogued as COSV56583357; called by muse, mutect2, varscan2
- CLCN6 | c.1769G>A p.W590* | Nonsense Mutation (SNP) | VAF 6/18 reads (33%) | catalogued as COSV56739278; called by muse, mutect2
- CLSPN | c.1423G>A p.E475K | Missense Mutation (SNP) | VAF 30/135 reads (22%) | SIFT tolerated (0.89); PolyPhen benign (0.003); catalogued as COSV52049262; called by muse, mutect2, varscan2
- CNGB1 | c.1567G>A p.E523K | Missense Mutation (SNP) | VAF 6/31 reads (19%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.643); catalogued as COSV51899761; called by muse, mutect2, varscan2
- CNKSR2 | c.2896G>C p.E966Q | Missense Mutation (SNP) | VAF 27/109 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV65279093; called by muse, mutect2, varscan2
- CNTN3 | c.2881G>A p.E961K | Missense Mutation (SNP) | VAF 29/91 reads (32%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.845); catalogued as COSV55167843; called by muse, mutect2, varscan2
- CNTN3 | c.1822G>A p.E608K | Missense Mutation (SNP) | VAF 23/79 reads (29%) | SIFT deleterious (0.03); PolyPhen benign (0.329); catalogued as COSV55174083; called by muse, mutect2, varscan2
- COBLL1 | c.401C>G p.S134* (on ENST00000392717; = p.S96* on NM_014900.5) | Nonsense Mutation (SNP) | VAF 37/109 reads (34%) | catalogued as COSV52066066; called by muse, mutect2, varscan2
- COG2 | c.1870G>A p.D624N | Missense Mutation (SNP) | VAF 6/40 reads (15%) | SIFT tolerated (0.51); PolyPhen benign (0.006); catalogued as COSV64186486; called by muse, mutect2
- COL13A1 | c.325G>A p.E109K | Missense Mutation (SNP) | VAF 10/22 reads (45%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.057); catalogued as rs1443556628, COSV62568600; called by muse, mutect2, varscan2
- COL17A1 | c.4096G>C p.D1366H | Missense Mutation (SNP) | VAF 10/40 reads (25%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.275); catalogued as COSV59824776; called by muse, mutect2
- COL24A1 | c.3446G>A p.G1149E | Missense Mutation (SNP) | VAF 7/57 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV65304723; called by muse, mutect2, varscan2
- COL25A1 | c.1178G>A p.R393K | Missense Mutation (SNP) | VAF 13/30 reads (43%) | SIFT tolerated (0.94); PolyPhen probably damaging (0.982); catalogued as COSV67648825; called by muse, mutect2, varscan2
- COL3A1 | c.1849C>T p.Q617* | Nonsense Mutation (SNP) | VAF 9/20 reads (45%) | catalogued as COSV58585530; called by muse, mutect2
- COL4A1 | c.824G>A p.G275E | Missense Mutation (SNP) | VAF 19/82 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.466); catalogued as COSV65423864; called by muse, mutect2, varscan2
- COL4A1 | c.805C>T p.Q269* | Nonsense Mutation (SNP) | VAF 8/26 reads (31%) | catalogued as COSV65423873; called by muse, mutect2, varscan2
- COL7A1 | c.8518G>C p.E2840Q | Missense Mutation (SNP) | VAF 12/41 reads (29%) | SIFT deleterious (0.02); PolyPhen benign (0.309); catalogued as COSV56476334; called by muse, mutect2, varscan2
- CPN2 | c.1380C>G p.D460E | Missense Mutation (SNP) | VAF 10/48 reads (21%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV60470118; called by muse, mutect2, varscan2
- CPT1C | c.1125C>G p.H375Q | Missense Mutation (SNP) | VAF 8/36 reads (22%) | SIFT tolerated (0.06); PolyPhen benign (0.003); catalogued as COSV99773263; called by mutect2, varscan2
- CPVL | c.574G>A p.E192K | Missense Mutation (SNP) | VAF 20/33 reads (61%) | SIFT tolerated (0.1); PolyPhen benign (0.281); catalogued as COSV55301209; called by muse, mutect2, varscan2
- CPZ | c.403G>A p.A135T (on ENST00000360986 / NM_001014447.3; = p.A124T on NM_003652.3) | Missense Mutation (SNP) | VAF 21/65 reads (32%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.938); catalogued as rs775620343, COSV59922528; called by muse, mutect2, varscan2
- CRX | c.871C>G p.Q291E | Missense Mutation (SNP) | VAF 6/30 reads (20%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.899); catalogued as COSV55757783; called by muse, mutect2
- CRY2 | c.136G>A p.G46R | Missense Mutation (SNP) | VAF 7/15 reads (47%) | SIFT tolerated (0.05); PolyPhen benign (0.289); catalogued as COSV69888370; called by muse, mutect2, varscan2
- CSGALNACT1 | c.728G>C p.R243P | Missense Mutation (SNP) | VAF 14/80 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV59976109; called by muse, mutect2
- CSMD3 | c.2854C>T p.H952Y (on ENST00000297405 / NM_001363185.1; = p.H848Y on NM_052900.3) | Missense Mutation (SNP) | VAF 10/30 reads (33%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.997); catalogued as COSV52149825, COSV52271001; called by muse, mutect2, varscan2
- CTPS2 | c.35C>A p.S12* | Nonsense Mutation (SNP) | VAF 14/74 reads (19%) | catalogued as COSV63722086; called by muse, mutect2, varscan2
- CTU2 | c.511G>A p.E171K | Missense Mutation (SNP) | VAF 14/52 reads (27%) | SIFT tolerated (0.75); PolyPhen benign (0.001); catalogued as rs748111545, COSV56335910; called by muse, mutect2, varscan2
- CUL5 | c.1967C>T p.S656L | Missense Mutation (SNP) | VAF 10/26 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.703); catalogued as COSV67608619; called by muse, mutect2, varscan2
- CYP27B1 | c.1034C>G p.S345* | Nonsense Mutation (SNP) | VAF 24/56 reads (43%) | catalogued as COSV99141512; called by muse, varscan2
- CYP2A6 | c.1467G>T p.M489I | Missense Mutation (SNP) | VAF 15/186 reads (8%) | SIFT tolerated (0.36); PolyPhen benign (0.006); catalogued as rs748123859, COSV99991742; called by muse, mutect2
- CYP2A7 | c.1467G>T p.M489I | Missense Mutation (SNP) | VAF 10/41 reads (24%) | SIFT tolerated (0.38); PolyPhen benign (0.019); catalogued as COSV52499955; called by muse, mutect2, varscan2
- CYP2C18 | c.136G>A p.D46N | Missense Mutation (SNP) | VAF 15/49 reads (31%) | SIFT tolerated (0.47); PolyPhen benign (0.018); catalogued as COSV53671275; called by muse, mutect2, varscan2
- CYP4F3 | c.1495C>T p.R499C | Missense Mutation (SNP) | VAF 24/86 reads (28%) | SIFT deleterious (0.03); PolyPhen benign (0.12); catalogued as COSV55408570; called by muse, mutect2, varscan2
- CYTH1 | c.973G>C p.E325Q | Missense Mutation (SNP) | VAF 5/24 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV63119736; called by muse, mutect2, varscan2
- DBNL | c.688G>A p.E230K | Missense Mutation (SNP) | VAF 7/19 reads (37%) | SIFT tolerated (0.12); PolyPhen benign (0); catalogued as rs541074419, COSV51977588; called by muse, mutect2, varscan2
- DCST1 | c.151C>G p.L51V | Missense Mutation (SNP) | VAF 19/84 reads (23%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.556); catalogued as COSV55051041; called by muse, mutect2, varscan2
- DGKG | c.388G>A p.E130K | Missense Mutation (SNP) | VAF 12/52 reads (23%) | SIFT tolerated (0.25); PolyPhen benign (0.001); catalogued as rs1161449602, COSV53963510; called by muse, mutect2, varscan2
- DHX36 | c.1949G>A p.G650E | Missense Mutation (SNP) | VAF 17/75 reads (23%) | SIFT tolerated (0.71); PolyPhen benign (0.007); catalogued as rs747063807, COSV57671798; called by muse, mutect2, varscan2
- DLG1 | c.76G>A p.E26K | Missense Mutation (SNP) | VAF 6/52 reads (12%) | SIFT tolerated (0.11); PolyPhen benign (0.089); catalogued as COSV58380292; called by mutect2, varscan2
- DMXL2 | c.8326C>G p.Q2776E | Missense Mutation (SNP) | VAF 7/23 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.949); catalogued as COSV51844072; called by muse, mutect2, varscan2
- DNAH10 | c.12234C>G p.F4078L (on ENST00000409039; = p.F4017L on NM_207437.3) | Missense Mutation (SNP) | VAF 14/50 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.831); catalogued as COSV68991406; called by muse, mutect2, varscan2
- DNAH2 | c.3595G>C p.E1199Q | Missense Mutation (SNP) | VAF 9/25 reads (36%) | SIFT tolerated (0.43); PolyPhen benign (0.017); catalogued as COSV66718471; called by muse, mutect2, varscan2
- DOCK6 | c.3445G>A p.D1149N | Missense Mutation (SNP) | VAF 6/28 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV53913320; called by muse, varscan2
- DOP1B | c.2611G>A p.D871N | Missense Mutation (SNP) | VAF 14/44 reads (32%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.907); catalogued as COSV67692905; called by muse, mutect2, varscan2
- DPP10 | c.1091C>T p.S364L | Missense Mutation (SNP) | VAF 4/70 reads (6%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.948); catalogued as COSV100059355; called by muse, mutect2
- DPP6 | c.476G>A p.R159K (on ENST00000377770 / NM_001364500.2; = p.R97K on NM_001936.5) | Missense Mutation (SNP) | VAF 11/19 reads (58%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.791); catalogued as COSV59606635; called by muse, mutect2, varscan2
- DPYD | c.3034G>T p.E1012* | Nonsense Mutation (SNP) | VAF 20/68 reads (29%) | catalogued as rs761584058, COSV64591675, COSV64594672; called by muse, mutect2, varscan2
- DSG2 | c.2915C>T p.S972F | Missense Mutation (SNP) | VAF 17/45 reads (38%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.87); catalogued as rs751064437, COSV55198296; called by muse, mutect2, varscan2
- DUSP16 | c.1592C>G p.S531C | Missense Mutation (SNP) | VAF 13/37 reads (35%) | SIFT deleterious (0.04); PolyPhen benign (0.43); catalogued as COSV53807211; called by muse, mutect2, varscan2
- EEF1G | c.965G>A p.W322* | Nonsense Mutation (SNP) | VAF 9/39 reads (23%) | catalogued as COSV61321342; called by muse, mutect2, varscan2
- EID2 | c.660C>G p.I220M | Missense Mutation (SNP) | VAF 6/76 reads (8%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.997); catalogued as COSV101180475; called by muse, mutect2
- ELAVL4 | c.458C>T p.S153L | Missense Mutation (SNP) | VAF 24/88 reads (27%) | SIFT deleterious (0.02); PolyPhen benign (0.191); catalogued as rs1175579240, COSV63915417; called by muse, mutect2, varscan2
- ELMO2 | c.985G>C p.D329H | Missense Mutation (SNP) | VAF 20/68 reads (29%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.897); catalogued as COSV51682418; called by muse, mutect2, varscan2
- EML3 | c.1603G>C p.D535H | Missense Mutation (SNP) | VAF 7/22 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV53871490; called by muse, mutect2, varscan2
- EP300 | c.952C>G p.P318A | Missense Mutation (SNP) | VAF 8/33 reads (24%) | SIFT tolerated (0.25); PolyPhen benign (0.035); catalogued as rs762647727, COSV54330481; ClinVar: benign; called by muse, mutect2, varscan2
- EP300 | c.2221C>T p.Q741* | Nonsense Mutation (SNP) | VAF 12/46 reads (26%) | catalogued as COSV54330489; called by muse, mutect2, varscan2
- EP300 | c.6754G>T p.E2252* | Nonsense Mutation (SNP) | VAF 7/14 reads (50%) | catalogued as COSV54330500; called by muse, mutect2, varscan2
- EPHA2 | c.550G>A p.D184N | Missense Mutation (SNP) | VAF 16/35 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV64452731; called by muse, mutect2, varscan2
- EPHB1 | c.375G>T p.K125N | Missense Mutation (SNP) | VAF 16/60 reads (27%) | SIFT tolerated (0.56); PolyPhen benign (0.053); catalogued as COSV67658028; called by muse, mutect2, varscan2
- EPRS1 | c.1570C>T p.Q524* | Nonsense Mutation (SNP) | VAF 21/71 reads (30%) | catalogued as COSV65098291; called by muse, mutect2, varscan2
- ERAP1 | c.1225G>A p.E409K | Missense Mutation (SNP) | VAF 10/37 reads (27%) | SIFT tolerated (0.63); PolyPhen benign (0.048); catalogued as COSV57086841; called by muse, mutect2, varscan2
- ERI3 | c.167C>T p.S56L | Missense Mutation (SNP) | VAF 7/24 reads (29%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0); catalogued as rs201922019, COSV64831041; called by muse, mutect2, varscan2
- ESX1 | c.283G>C p.E95Q | Missense Mutation (SNP) | VAF 7/42 reads (17%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0.063); catalogued as COSV65424160; called by muse, mutect2
- ESYT2 | c.1040C>T p.S347L (on ENST00000613624; = p.S271L on NM_020728.3) | Missense Mutation (SNP) | VAF 15/38 reads (39%) | SIFT deleterious (0.01); PolyPhen benign (0.105); catalogued as COSV51749577; called by muse, mutect2, varscan2
- ETNPPL | c.982G>C p.E328Q | Missense Mutation (SNP) | VAF 7/46 reads (15%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.756); catalogued as COSV56595375; called by muse, mutect2, varscan2
- EXPH5 | c.4322G>C p.R1441T | Missense Mutation (SNP) | VAF 7/21 reads (33%) | SIFT tolerated (0.58); PolyPhen benign (0.185); catalogued as COSV56200871; called by muse, mutect2, varscan2
- FAM209A | c.334G>T p.A112S | Missense Mutation (SNP) | VAF 12/38 reads (32%) | SIFT tolerated (0.05); PolyPhen benign (0.133); catalogued as rs751585330, COSV54766664; called by muse, mutect2, varscan2
- FAM71A | c.1539G>A p.W513* | Nonsense Mutation (SNP) | VAF 18/65 reads (28%) | catalogued as COSV54235287; called by muse, mutect2, varscan2
- FAM83G | c.262C>T p.Q88* | Nonsense Mutation (SNP) | VAF 16/55 reads (29%) | catalogued as COSV58756629, COSV58759158; called by muse, mutect2, varscan2
- FARP1 | c.250G>C p.E84Q | Missense Mutation (SNP) | VAF 13/51 reads (25%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.996); catalogued as COSV60334456; called by muse, mutect2, varscan2
- FAT1 | c.13118C>T p.S4373F | Missense Mutation (SNP) | VAF 13/35 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV71673318; called by muse, mutect2, varscan2
- FBH1 | c.2199G>A p.Q733= (on ENST00000362091 / NM_178150.3; = p.Q784= on NM_032807.4) | Splice Region (SNP) | VAF 17/61 reads (28%) | catalogued as COSV100758620; called by muse, mutect2, varscan2
- FCRL4 | c.1235G>A p.R412H | Missense Mutation (SNP) | VAF 7/28 reads (25%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs557777677, COSV54861454; called by muse, mutect2
- FIGN | c.179C>T p.S60F | Missense Mutation (SNP) | VAF 12/48 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV60765506; called by muse, mutect2, varscan2
- FITM1 | c.436G>A p.E146K | Missense Mutation (SNP) | VAF 10/26 reads (38%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.875); catalogued as rs759275530, COSV52823809, COSV52825607; called by muse, mutect2, varscan2
- FKBP10 | c.1340G>A p.C447Y | Missense Mutation (SNP) | VAF 16/42 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54055406; called by muse, mutect2, varscan2
- FLG | c.6205C>T p.Q2069* | Nonsense Mutation (SNP) | VAF 73/388 reads (19%) | catalogued as COSV64240093; called by muse, mutect2
- FLG2 | c.2615G>C p.G872A | Missense Mutation (SNP) | VAF 60/223 reads (27%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.677); catalogued as COSV66167874; called by muse, mutect2, varscan2
- FLNA | c.2461G>A p.D821N | Missense Mutation (SNP) | VAF 48/176 reads (27%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as COSV100774535, COSV61041054; called by muse, mutect2, varscan2
- FLNB | c.6281G>A p.R2094K | Missense Mutation (SNP) | VAF 22/82 reads (27%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.989); catalogued as COSV55876134; called by muse, mutect2, varscan2
- FLRT2 | c.1235A>G p.D412G | Missense Mutation (SNP) | VAF 15/33 reads (45%) | SIFT tolerated (0.46); PolyPhen benign (0.007); catalogued as COSV100420042; called by muse, mutect2, varscan2
- FOCAD | c.3094G>A p.E1032K | Missense Mutation (SNP) | VAF 17/61 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as COSV58096818; called by muse, mutect2, varscan2
- FREM1 | c.463G>A p.D155N | Missense Mutation (SNP) | VAF 22/49 reads (45%) | SIFT tolerated (0.17); PolyPhen benign (0.13); catalogued as COSV66521623; called by muse, mutect2, varscan2
- GAA | c.1961C>T p.S654L | Missense Mutation (SNP) | VAF 22/53 reads (42%) | SIFT deleterious (0); PolyPhen benign (0.41); catalogued as COSV100163390, COSV56407958; called by muse, mutect2, varscan2
- GCC2 | c.4263G>A p.M1421I | Missense Mutation (SNP) | VAF 5/27 reads (19%) | SIFT tolerated (0.09); PolyPhen benign (0.006); catalogued as COSV59175500; called by muse, mutect2, varscan2
- GCFC2 | c.2287G>A p.E763K | Missense Mutation (SNP) | VAF 18/73 reads (25%) | SIFT tolerated (0.12); PolyPhen benign (0.005); catalogued as COSV58080530; called by muse, mutect2, varscan2
- GCNA | c.1178C>G p.S393* | Nonsense Mutation (SNP) | VAF 7/42 reads (17%) | catalogued as COSV65466424; called by muse, mutect2, varscan2
- GHR | c.1420C>T p.Q474* | Nonsense Mutation (SNP) | VAF 29/59 reads (49%) | catalogued as COSV50109662; called by muse, mutect2, varscan2
- GMEB1 | c.1322C>T p.S441F | Missense Mutation (SNP) | VAF 9/52 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.737); catalogued as rs867578898, COSV53793923; called by muse, mutect2, varscan2
- GMNN | c.179C>G p.S60C | Missense Mutation (SNP) | VAF 28/66 reads (42%) | SIFT deleterious (0); PolyPhen possibly damaging (0.866); catalogued as COSV57776746; called by muse, mutect2, varscan2
- GNAT2 | c.496G>C p.E166Q | Missense Mutation (SNP) | VAF 33/89 reads (37%) | SIFT deleterious (0.03); PolyPhen benign (0.088); catalogued as COSV63554761; called by muse, mutect2, varscan2
- GPR101 | c.827G>C p.R276T | Missense Mutation (SNP) | VAF 37/129 reads (29%) | SIFT tolerated (0.61); PolyPhen benign (0.011); catalogued as COSV53238509; called by muse, mutect2, varscan2
- GPRASP1 | c.1100C>T p.S367L | Missense Mutation (SNP) | VAF 5/23 reads (22%) | SIFT tolerated (0.27); PolyPhen benign (0); catalogued as COSV64354689, COSV64355331; called by muse, mutect2, varscan2
- GRHL2 | c.440C>T p.S147F | Missense Mutation (SNP) | VAF 14/31 reads (45%) | SIFT tolerated (0.06); PolyPhen benign (0.396); catalogued as COSV52547060; called by muse, mutect2, varscan2
- GRIK1 | c.2407G>A p.E803K | Missense Mutation (SNP) | VAF 16/48 reads (33%) | SIFT tolerated (0.63); PolyPhen possibly damaging (0.654); catalogued as COSV100515948; called by muse, mutect2, varscan2
- GSDMA | c.193G>C p.E65Q | Missense Mutation (SNP) | VAF 6/21 reads (29%) | SIFT tolerated (0.06); PolyPhen benign (0.229); catalogued as COSV100053534; called by muse, varscan2
- GTF3C1 | c.4801G>A p.E1601K | Missense Mutation (SNP) | VAF 13/67 reads (19%) | SIFT deleterious (0.01); PolyPhen benign (0.326); catalogued as COSV100649460, COSV62240220; called by muse, mutect2, varscan2
- H2BC14 | c.275C>T p.S92L | Missense Mutation (SNP) | VAF 36/93 reads (39%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.595); catalogued as rs1474071318, COSV60797493, COSV60797855; called by muse, mutect2, varscan2
- HCAR3 | c.1072C>G p.L358V | Missense Mutation (SNP) | VAF 36/76 reads (47%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.007); catalogued as COSV63673344; called by muse, varscan2
- HCFC1 | c.5741C>T p.S1914F | Missense Mutation (SNP) | VAF 16/43 reads (37%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.641); catalogued as rs782810696, COSV60071271; called by muse, mutect2, varscan2
- HLA-A | c.896-1G>C p.X299_splice | Splice Site (SNP) | VAF 54/330 reads (16%) | catalogued as COSV65139440; called by muse, mutect2, varscan2
- HLA-B | c.127G>T p.E43* | Nonsense Mutation (SNP) | VAF 8/50 reads (16%) | catalogued as rs137854653, CM1412111, COSV69520364, COSV69521019; called by mutect2, varscan2
- HLA-DQA1 | c.151G>C p.E51Q | Missense Mutation (SNP) | VAF 21/54 reads (39%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as COSV58238324, COSV58240182; called by muse, mutect2
- HLX | c.958G>A p.V320M | Missense Mutation (SNP) | VAF 10/44 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV65044640; called by muse, mutect2, varscan2
- HMGXB4 | c.244G>A p.D82N | Missense Mutation (SNP) | VAF 35/74 reads (47%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.877); catalogued as COSV53333501; called by muse, mutect2, varscan2
- HNRNPU | c.2081G>C p.G694A (on ENST00000283179; = p.G756A on NM_004501.3) | Missense Mutation (SNP) | VAF 7/107 reads (7%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.992); catalogued as COSV99309946; called by muse, mutect2
- HOXA1 | c.278C>G p.S93* | Nonsense Mutation (SNP) | VAF 14/63 reads (22%) | catalogued as COSV99761028; called by muse, mutect2, varscan2
- HOXA7 | c.89C>T p.S30F | Missense Mutation (SNP) | VAF 7/35 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.592); catalogued as rs755438662, COSV54217230; called by muse, mutect2, varscan2
- HOXB2 | c.50C>T p.S17L | Missense Mutation (SNP) | VAF 22/60 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.662); catalogued as COSV57486405; called by muse, mutect2, varscan2
- HPGD | c.769G>C p.D257H | Missense Mutation (SNP) | VAF 17/49 reads (35%) | SIFT tolerated (0.09); PolyPhen benign (0.121); catalogued as COSV56662053; called by muse, mutect2, varscan2
- HPR | c.886G>A p.D296N | Missense Mutation (SNP) | VAF 22/124 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs780251908, COSV57182212; called by muse, mutect2, varscan2
- HRC | c.1846C>G p.Q616E | Missense Mutation (SNP) | VAF 7/51 reads (14%) | SIFT deleterious (0.05); PolyPhen benign (0.018); catalogued as COSV99417563; called by muse, mutect2, varscan2
- HSPA12A | c.1769C>T p.P590L | Missense Mutation (SNP) | VAF 9/26 reads (35%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.867); catalogued as rs781953547, COSV65021800; called by muse, varscan2
- HTR6 | c.1079C>T p.P360L | Missense Mutation (SNP) | VAF 8/32 reads (25%) | SIFT deleterious (0.01); PolyPhen benign (0.073); catalogued as COSV53871632; called by muse, mutect2
- IFT122 | c.1581G>C p.K527N (on ENST00000348417 / NM_052989.3; = p.K468N on NM_018262.4) | Missense Mutation (SNP) | VAF 19/86 reads (22%) | SIFT tolerated (0.78); PolyPhen benign (0); catalogued as COSV56201959; called by muse, mutect2, varscan2
- IGSF11 | c.1142C>T p.S381L (on ENST00000393775 / NM_001015887.3; = p.S380L on NM_152538.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 25/100 reads (25%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.522); catalogued as COSV61168126; called by muse, mutect2, varscan2
- IL1RAP | c.685C>G p.L229V | Missense Mutation (SNP) | VAF 6/73 reads (8%) | SIFT tolerated (0.53); PolyPhen benign (0); catalogued as COSV99299052; called by muse, mutect2
- IL4I1 | c.83G>A p.R28H | Missense Mutation (SNP) | VAF 30/88 reads (34%) | SIFT tolerated (0.72); PolyPhen benign (0); catalogued as rs141664132; called by muse, mutect2, varscan2
- INPP4B | c.664G>C p.D222H | Missense Mutation (SNP) | VAF 31/65 reads (48%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.695); catalogued as COSV53719595, COSV53725490; called by muse, mutect2, varscan2
- IPP | c.214G>A p.E72K | Missense Mutation (SNP) | VAF 14/44 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.987); catalogued as COSV63432388; called by muse, mutect2, varscan2
- IQGAP2 | c.115G>A p.E39K | Missense Mutation (SNP) | VAF 18/60 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.528); catalogued as rs760630948, COSV57171697; called by muse, mutect2, varscan2
- IREB2 | c.152G>A p.R51Q | Missense Mutation (SNP) | VAF 17/58 reads (29%) | SIFT deleterious (0); PolyPhen benign (0.247); catalogued as COSV51924863; called by muse, varscan2
- IREB2 | c.2283C>G p.I761M | Missense Mutation (SNP) | VAF 10/52 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV51921795, COSV51922389; called by muse, mutect2, varscan2
- IRS4 | c.3452C>T p.A1151V | Missense Mutation (SNP) | VAF 10/34 reads (29%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.003); catalogued as rs992081802, COSV100929440; called by muse, varscan2
- ITGA9 | c.2431C>T p.Q811* | Nonsense Mutation (SNP) | VAF 8/32 reads (25%) | catalogued as COSV53240079; called by muse, mutect2, varscan2
- ITGAM | c.2519C>T p.S840L (on ENST00000648685 / NM_001145808.2; = p.S839L on NM_000632.4) | Missense Mutation (SNP) | VAF 19/73 reads (26%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.482); catalogued as COSV54935973; called by muse, mutect2, varscan2
- ITGB1BP2 | c.986C>T p.S329L | Missense Mutation (SNP) | VAF 8/30 reads (27%) | SIFT tolerated (0.1); PolyPhen benign (0.407); catalogued as COSV52136959; called by muse, mutect2
- ITPR1 | c.5439G>A p.M1813I (on ENST00000354582; = p.M1758I on NM_002222.7) | Missense Mutation (SNP) | VAF 23/81 reads (28%) | SIFT tolerated (0.73); PolyPhen benign (0.012); catalogued as COSV56976854; called by muse, mutect2, varscan2
- ITPR1 | c.8181G>C p.R2727S (on ENST00000354582; = p.R2672S on NM_002222.7) | Missense Mutation (SNP) | VAF 19/49 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV56976878; called by muse, mutect2, varscan2
- JCAD | c.3786G>A p.M1262I | Missense Mutation (SNP) | VAF 5/20 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV64758969; called by muse, mutect2, varscan2
- JMY | c.1384C>T p.Q462* | Nonsense Mutation (SNP) | VAF 11/32 reads (34%) | catalogued as COSV68660496; called by muse, mutect2, varscan2
- KCNA2 | c.403G>A p.E135K | Missense Mutation (SNP) | VAF 12/30 reads (40%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.655); catalogued as COSV60369636; called by muse, mutect2, varscan2
- KCNF1 | c.472G>A p.E158K | Missense Mutation (SNP) | VAF 6/46 reads (13%) | SIFT tolerated (0.6); PolyPhen benign (0.052); catalogued as rs773536391, COSV54462309, COSV54464047; called by muse, mutect2
- KCNH4 | c.2044C>G p.R682G | Missense Mutation (SNP) | VAF 28/49 reads (57%) | SIFT tolerated (0.22); PolyPhen benign (0.01); catalogued as COSV52916599; called by muse, mutect2, varscan2
- KDM5C | c.3847G>A p.E1283K | Missense Mutation (SNP) | VAF 22/78 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV64764264; called by muse, mutect2, varscan2
- KHSRP | c.1051G>C p.D351H | Missense Mutation (SNP) | VAF 4/68 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as COSV101231135, COSV67919263; called by muse, mutect2
- KIAA1549L | c.3176G>A p.W1059* (on ENST00000321505; = p.W1356* on NM_012194.3) | Nonsense Mutation (SNP) | VAF 6/48 reads (13%) | catalogued as COSV55771921; called by muse, mutect2, varscan2
- KIF11 | c.388G>C p.D130H | Missense Mutation (SNP) | VAF 25/72 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53269957; called by muse, mutect2, varscan2
- KIF1B | c.697G>A p.E233K | Missense Mutation (SNP) | VAF 8/42 reads (19%) | SIFT tolerated (0.24); PolyPhen benign (0.007); catalogued as COSV55806731; called by muse, mutect2, varscan2
- KIF3B | c.2026G>A p.E676K | Missense Mutation (SNP) | VAF 10/47 reads (21%) | SIFT deleterious (0.05); PolyPhen benign (0.162); catalogued as COSV65227298; called by muse, mutect2, varscan2
- KLB | c.2384G>A p.R795Q | Missense Mutation (SNP) | VAF 22/49 reads (45%) | SIFT tolerated (0.48); PolyPhen benign (0.018); catalogued as COSV99961964; called by muse, mutect2, varscan2
- KLC3 | c.403G>C p.E135Q | Missense Mutation (SNP) | VAF 5/22 reads (23%) | SIFT tolerated (1); PolyPhen benign (0.009); catalogued as COSV67272281, COSV67272961; called by muse, mutect2, varscan2
- KLHL38 | c.1089G>C p.W363C | Missense Mutation (SNP) | VAF 13/35 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58086849; called by muse, mutect2, varscan2
- KLHL5 | c.676G>A p.A226T | Missense Mutation (SNP) | VAF 28/77 reads (36%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.946); catalogued as rs758479877, COSV54673281; called by muse, mutect2, varscan2
- KLHL5 | c.1487C>T p.P496L | Missense Mutation (SNP) | VAF 16/39 reads (41%) | SIFT tolerated (0.81); PolyPhen benign (0.247); catalogued as COSV54673318; called by muse, mutect2, varscan2
- KLRC4 | c.413G>C p.R138T | Missense Mutation (SNP) | VAF 4/88 reads (5%) | SIFT tolerated (0.34); PolyPhen benign (0.063); catalogued as COSV100511252; called by muse, mutect2
- KMT2C | c.6658C>T p.Q2220* | Nonsense Mutation (SNP) | VAF 58/146 reads (40%) | catalogued as COSV51352652; called by muse, mutect2, varscan2
- KMT2C | c.6481C>T p.Q2161* | Nonsense Mutation (SNP) | VAF 13/32 reads (41%) | catalogued as COSV51427691; called by muse, mutect2, varscan2
- KMT2C | c.1767G>C p.K589N | Missense Mutation (SNP) | VAF 27/60 reads (45%) | SIFT tolerated (0.19); PolyPhen benign (0); catalogued as COSV51427709; called by muse, mutect2, varscan2
- KRT75 | c.857C>A p.S286* | Nonsense Mutation (SNP) | VAF 10/30 reads (33%) | catalogued as COSV52872007; called by muse, mutect2, varscan2
- KRTAP10-8 | c.119C>T p.S40F | Missense Mutation (SNP) | VAF 18/47 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1555931154, COSV58165797; called by muse, mutect2, varscan2
- KTI12 | c.370G>A p.E124K | Missense Mutation (SNP) | VAF 11/34 reads (32%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.012); catalogued as rs774458515, COSV65405706; called by muse, mutect2, varscan2
- LAMB2 | c.3761C>T p.S1254F | Missense Mutation (SNP) | VAF 9/50 reads (18%) | SIFT deleterious (0.01); PolyPhen benign (0.003); catalogued as COSV59732482; called by muse, mutect2, varscan2
- LAMB2 | c.2930C>G p.S977* | Nonsense Mutation (SNP) | VAF 8/38 reads (21%) | catalogued as COSV59732497; called by muse, mutect2, varscan2
- LAMC2 | c.2605G>T p.E869* | Nonsense Mutation (SNP) | VAF 12/49 reads (24%) | catalogued as COSV51454367; called by muse, mutect2, varscan2
- LAMC2 | c.2747G>A p.G916E | Missense Mutation (SNP) | VAF 9/45 reads (20%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs777067409, COSV51454380; called by muse, mutect2, varscan2
- LDAH | c.22G>A p.E8K | Missense Mutation (SNP) | VAF 6/26 reads (23%) | SIFT tolerated (0.14); PolyPhen benign (0.057); catalogued as COSV52969515; called by muse, mutect2, varscan2
- LEFTY2 | c.1064C>T p.S355L | Missense Mutation (SNP) | VAF 6/52 reads (12%) | SIFT tolerated (0.24); PolyPhen benign (0.196); catalogued as rs766277265, COSV64746692; called by mutect2, varscan2
- LGR5 | c.2680G>A p.E894K | Missense Mutation (SNP) | VAF 6/24 reads (25%) | SIFT deleterious (0.01); PolyPhen benign (0.293); catalogued as rs766795698, COSV57010752; called by muse, mutect2
- LIMD1 | c.1079C>T p.S360L | Missense Mutation (SNP) | VAF 12/37 reads (32%) | SIFT tolerated (0.38); PolyPhen benign (0); catalogued as COSV56266724; called by muse, mutect2, varscan2
- LINS1 | c.28G>A p.E10K | Missense Mutation (SNP) | VAF 4/25 reads (16%) | SIFT deleterious (0.02); PolyPhen benign (0.006); catalogued as COSV59078595, COSV59080068; called by muse, mutect2
- LIPI | c.1301C>T p.S434F | Missense Mutation (SNP) | VAF 25/54 reads (46%) | SIFT tolerated (0.08); PolyPhen benign (0.011); catalogued as COSV60710154; called by muse, mutect2, varscan2
- LMLN | c.316G>C p.E106Q | Missense Mutation (SNP) | VAF 22/71 reads (31%) | SIFT tolerated (0.3); PolyPhen benign (0.038); catalogued as COSV57599541; called by muse, mutect2, varscan2
- LMO1 | c.178G>A p.E60K | Missense Mutation (SNP) | VAF 11/59 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.769); catalogued as rs776473765, COSV59956964, COSV59958654; called by muse, mutect2, varscan2
- LMO7 | c.84C>G p.I28M (on ENST00000357063; = p.I43M on NM_005358.5) | Missense Mutation (SNP) | VAF 13/57 reads (23%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.516); catalogued as COSV58533347; called by muse, mutect2, varscan2
- LRP1B | c.2056C>T p.R686W | Missense Mutation (SNP) | VAF 15/22 reads (68%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs767797300, COSV67264248; called by muse, varscan2
- LRR1 | c.464C>G p.S155C | Missense Mutation (SNP) | VAF 8/48 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.594); catalogued as COSV53562682, COSV53563042; called by muse, mutect2, varscan2
- LRRC8E | c.1037C>T p.S346F | Missense Mutation (SNP) | VAF 11/29 reads (38%) | SIFT tolerated (0.62); PolyPhen benign (0.003); catalogued as COSV60717594; called by muse, mutect2, varscan2
- LRRK2 | c.5204G>A p.R1735Q | Missense Mutation (SNP) | VAF 11/31 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.952); catalogued as rs779100383, COSV54149512; called by muse, mutect2, varscan2
- LUC7L | c.740G>C p.R247T | Missense Mutation (SNP) | VAF 12/67 reads (18%) | SIFT deleterious (0.03); PolyPhen benign (0.432); catalogued as COSV53457933; called by muse, mutect2, varscan2
- MAGI1 | c.1477G>A p.D493N | Missense Mutation (SNP) | VAF 19/86 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100439471; called by muse, mutect2, varscan2
- MARS1 | c.638G>A p.G213E | Missense Mutation (SNP) | VAF 9/24 reads (38%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV56253805; called by muse, mutect2, varscan2
- MAT2A | c.1112A>C p.Y371S | Missense Mutation (SNP) | VAF 11/31 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV52087758; called by muse, mutect2, varscan2
- MB21D2 | c.931C>T p.Q311* | Nonsense Mutation (SNP) | VAF 5/18 reads (28%) | catalogued as COSV66661548, COSV66661553; called by muse, mutect2, varscan2
- MDN1 | c.13381G>A p.E4461K | Missense Mutation (SNP) | VAF 13/66 reads (20%) | SIFT tolerated (0.56); PolyPhen benign (0); catalogued as COSV65520162; called by muse, mutect2, varscan2
- MDN1 | c.2740G>A p.E914K | Missense Mutation (SNP) | VAF 15/62 reads (24%) | SIFT tolerated (0.56); PolyPhen benign (0.013); catalogued as COSV65520166; called by muse, mutect2, varscan2
- MEIS2 | c.992G>A p.R331K (on ENST00000561208 / NM_170675.5; = p.R318K on NM_002399.3) | Missense Mutation (SNP) | VAF 21/66 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54933755; called by muse, mutect2, varscan2
- MEP1A | c.574G>C p.D192H | Missense Mutation (SNP) | VAF 18/39 reads (46%) | SIFT deleterious (0.01); PolyPhen benign (0.026); catalogued as COSV57919342; called by muse, mutect2, varscan2
- MMP12 | c.865G>C p.D289H | Missense Mutation (SNP) | VAF 32/87 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV58259545; called by muse, mutect2, varscan2
- MPP7 | c.905G>A p.R302Q | Missense Mutation (SNP) | VAF 8/12 reads (67%) | SIFT tolerated (0.15); PolyPhen benign (0.018); catalogued as rs775616676, COSV61731378; called by muse, mutect2, varscan2
- MSTO1 | c.364G>C p.E122Q | Missense Mutation (SNP) | VAF 13/79 reads (16%) | SIFT tolerated (0.22); PolyPhen benign (0.041); catalogued as COSV55471734; called by muse, mutect2, varscan2
- MTDH | c.1677G>C p.Q559H | Missense Mutation (SNP) | VAF 8/68 reads (12%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.997); catalogued as COSV60343510; called by muse, mutect2, varscan2
- MTHFD1 | c.1318C>T p.L440F | Missense Mutation (SNP) | VAF 10/18 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV53699482; called by muse, mutect2, varscan2
- MUC17 | c.3230C>G p.S1077C | Missense Mutation (SNP) | VAF 16/130 reads (12%) | SIFT deleterious (0); PolyPhen benign (0.184); catalogued as COSV100071772; called by muse, mutect2, varscan2
- MUC5B | c.10978G>A p.E3660K | Missense Mutation (SNP) | VAF 11/24 reads (46%) | SIFT tolerated (0.63); PolyPhen benign (0.428); catalogued as COSV71591262; called by muse, mutect2, varscan2
- MUC5B | c.14177C>T p.S4726F | Missense Mutation (SNP) | VAF 43/101 reads (43%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.447); catalogued as rs760293801, COSV101500267, COSV71591265; called by muse, mutect2, varscan2
- MXI1 | c.182C>T p.S61L | Missense Mutation (SNP) | VAF 10/30 reads (33%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.042); catalogued as COSV60312529; called by muse, mutect2, varscan2
- MXRA5 | c.8159C>T p.S2720L | Missense Mutation (SNP) | VAF 15/69 reads (22%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.993); catalogued as rs767370839, COSV54230053; called by muse, mutect2, varscan2
- MYH9 | c.730G>A p.D244N | Missense Mutation (SNP) | VAF 15/50 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.79); catalogued as COSV53384459; called by muse, mutect2, varscan2
- MYO1B | c.1288G>A p.E430K | Missense Mutation (SNP) | VAF 7/14 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV58429616; called by muse, mutect2, varscan2
- MYPN | c.3929C>G p.S1310C | Missense Mutation (SNP) | VAF 28/67 reads (42%) | SIFT tolerated (0.08); PolyPhen benign (0.302); catalogued as COSV62732900; called by muse, mutect2, varscan2
- NAB2 | c.44G>A p.G15E | Missense Mutation (SNP) | VAF 21/53 reads (40%) | SIFT tolerated, low confidence (0.43); PolyPhen probably damaging (0.972); catalogued as rs775578240, COSV100272449, COSV55665987; called by muse, mutect2, varscan2
- NACC1 | c.856G>A p.E286K | Missense Mutation (SNP) | VAF 3/40 reads (8%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.767); catalogued as COSV99456790; called by muse, mutect2
- NAV3 | c.5288C>T p.S1763F | Missense Mutation (SNP) | VAF 13/34 reads (38%) | SIFT deleterious (0.01); PolyPhen benign (0.185); catalogued as COSV57073177; called by muse, mutect2, varscan2
- NCAPD2 | c.1085G>A p.R362K | Missense Mutation (SNP) | VAF 16/56 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV59698747; called by muse, mutect2, varscan2
- NCAPD3 | c.652C>T p.H218Y | Missense Mutation (SNP) | VAF 8/30 reads (27%) | SIFT tolerated (1); PolyPhen benign (0.037); catalogued as COSV73257880; called by muse, mutect2, varscan2
- NCDN | c.1223C>T p.S408L | Missense Mutation (SNP) | VAF 40/135 reads (30%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.769); catalogued as COSV61935333; called by muse, mutect2, varscan2
- NEO1 | c.191C>T p.S64L | Missense Mutation (SNP) | VAF 4/18 reads (22%) | SIFT deleterious (0.04); PolyPhen benign (0.102); catalogued as COSV56069841; called by muse, mutect2
- NETO1 | c.310C>T p.R104* | Nonsense Mutation (SNP) | VAF 13/40 reads (33%) | catalogued as rs751414283, COSV55002931; called by muse, mutect2, varscan2
- NFATC2 | c.127G>A p.E43K | Missense Mutation (SNP) | VAF 12/77 reads (16%) | SIFT tolerated (0.29); PolyPhen benign (0.16); catalogued as COSV65354780; called by muse, mutect2, varscan2
- NFATC4 | c.2213C>T p.S738L | Missense Mutation (SNP) | VAF 4/38 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.535); catalogued as COSV51596793, COSV51599783; called by muse, mutect2, varscan2
- NHLH2 | c.279C>A p.F93L | Missense Mutation (SNP) | VAF 13/55 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.977); catalogued as COSV57201924; called by muse, mutect2, varscan2
- NKTR | c.341G>A p.R114Q | Missense Mutation (SNP) | VAF 14/62 reads (23%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as COSV51770949, COSV99236362; called by muse, mutect2, varscan2
- NLRP14 | c.3232G>A p.D1078N | Missense Mutation (SNP) | VAF 28/64 reads (44%) | SIFT tolerated (0.31); PolyPhen benign (0.001); catalogued as COSV100204614; called by muse, mutect2, varscan2
- NLRP5 | c.3491C>T p.P1164L | Missense Mutation (SNP) | VAF 17/64 reads (27%) | SIFT deleterious (0.03); PolyPhen benign (0.392); catalogued as COSV101173713, COSV66763586; called by muse, mutect2, varscan2
- NLRP9 | c.2621G>C p.R874T | Missense Mutation (SNP) | VAF 13/31 reads (42%) | SIFT deleterious (0.05); PolyPhen benign (0.155); catalogued as COSV60461904, COSV60465034; called by muse, mutect2, varscan2
- NME8 | c.1563G>A p.M521I | Missense Mutation (SNP) | VAF 18/34 reads (53%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.728); catalogued as COSV52247006; called by muse, mutect2, varscan2
- NMT1 | c.10G>A p.E4K | Missense Mutation (SNP) | VAF 11/35 reads (31%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.017); catalogued as rs983223652, COSV51959184; called by muse, mutect2, varscan2
- NOL6 | c.2467G>A p.A823T | Missense Mutation (SNP) | VAF 13/34 reads (38%) | SIFT deleterious (0.02); PolyPhen benign (0.425); catalogued as COSV53040856; called by muse, mutect2, varscan2
- NOS3 | c.28G>A p.E10K | Missense Mutation (SNP) | VAF 8/28 reads (29%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.051); catalogued as rs547845670, COSV52488467, COSV52490566; called by muse, mutect2, varscan2
- NOX5 | c.1592G>C p.G531A | Missense Mutation (SNP) | VAF 17/68 reads (25%) | SIFT tolerated (0.57); PolyPhen benign (0.138); catalogued as COSV52987228; called by muse, mutect2, varscan2
- NSUN5 | c.1004C>T p.A335V | Missense Mutation (SNP) | VAF 6/24 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.932); catalogued as COSV53091245; called by muse, mutect2, varscan2
- NUGGC | c.1846G>C p.E616Q | Missense Mutation (SNP) | VAF 11/29 reads (38%) | SIFT tolerated (0.1); PolyPhen benign (0.198); catalogued as COSV58433956; called by muse, mutect2, varscan2
- NYAP2 | c.253G>A p.G85R | Missense Mutation (SNP) | VAF 20/43 reads (47%) | SIFT tolerated (0.27); PolyPhen possibly damaging (0.687); catalogued as COSV56002563, COSV56004189; called by muse, mutect2, varscan2
- OGT | c.2860C>T p.R954* | Nonsense Mutation (SNP) | VAF 32/138 reads (23%) | catalogued as COSV65480302; called by muse, mutect2, varscan2
- OR2M7 | c.117C>G p.F39L | Missense Mutation (SNP) | VAF 47/158 reads (30%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV58738626; called by muse, mutect2, varscan2
- OR51M1 | c.920A>C p.K307T | Missense Mutation (SNP) | VAF 13/37 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60784293; called by muse, mutect2, varscan2
- OR5AR1 | c.284C>G p.S95C | Missense Mutation (SNP) | VAF 8/37 reads (22%) | SIFT tolerated (0.16); PolyPhen benign (0.315); catalogued as COSV57253460, COSV57255300; called by muse, mutect2, varscan2
- OR5F1 | c.689C>T p.S230L | Missense Mutation (SNP) | VAF 7/18 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.69); catalogued as rs762358931, COSV53545988, COSV53549109; called by muse, mutect2, varscan2
- OR5F1 | c.59C>T p.T20M | Missense Mutation (SNP) | VAF 5/14 reads (36%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.549); catalogued as rs753933467, COSV53545997; called by muse, mutect2, varscan2
- ORC1 | c.208G>C p.E70Q | Missense Mutation (SNP) | VAF 8/96 reads (8%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.886); catalogued as COSV57122567, COSV99933184; called by muse, mutect2
- P2RY14 | c.319G>A p.V107I | Missense Mutation (SNP) | VAF 14/47 reads (30%) | SIFT tolerated (0.93); PolyPhen benign (0.019); catalogued as rs777331242, COSV56375115; called by muse, mutect2, varscan2
- P4HA2 | c.215C>T p.S72L | Missense Mutation (SNP) | VAF 16/45 reads (36%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.643); catalogued as rs200158840, COSV51324454; called by muse, mutect2, varscan2
- PAF1 | c.499G>A p.E167K | Missense Mutation (SNP) | VAF 19/69 reads (28%) | SIFT tolerated (0.5); PolyPhen benign (0.082); catalogued as COSV55393349; called by muse, mutect2, varscan2
- PASD1 | c.1315G>A p.A439T | Missense Mutation (SNP) | VAF 17/93 reads (18%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs370064836, COSV64854833; called by muse, mutect2, varscan2
- PCDH1 | c.3702G>C p.E1234D | Missense Mutation (SNP) | VAF 19/53 reads (36%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.09); catalogued as COSV54613033; called by muse, mutect2, varscan2
- PCDH15 | c.2440G>A p.D814N | Missense Mutation (SNP) | VAF 5/62 reads (8%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.925); catalogued as rs867920472, COSV100215804; called by muse, mutect2
- PCDH17 | c.1670C>T p.S557L | Missense Mutation (SNP) | VAF 4/24 reads (17%) | SIFT deleterious (0); PolyPhen benign (0.021); catalogued as rs938421179, COSV64973271; called by muse, mutect2, varscan2
- PCDHA6 | c.1038C>A p.N346K | Missense Mutation (SNP) | VAF 14/49 reads (29%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.98); catalogued as rs782009318, COSV65351150, COSV65355339; called by muse, mutect2, varscan2
- PCDHAC2 | c.2012C>T p.S671L | Missense Mutation (SNP) | VAF 20/53 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV53845045; called by muse, mutect2, varscan2
- PCDHGA9 | c.1396G>A p.A466T | Missense Mutation (SNP) | VAF 15/36 reads (42%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.166); catalogued as rs370966293, COSV53921726; called by muse, mutect2, varscan2
- PCK2 | c.996G>C p.W332C | Missense Mutation (SNP) | VAF 18/49 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV53748424; called by muse, mutect2, varscan2
- PCLO | c.15064G>A p.D5022N | Missense Mutation (SNP) | VAF 9/37 reads (24%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.964); catalogued as COSV61627268; called by muse, mutect2, varscan2
- PCYOX1 | c.10G>A p.V4I | Missense Mutation (SNP) | VAF 6/20 reads (30%) | SIFT tolerated, low confidence (0.3); PolyPhen benign (0.005); catalogued as COSV52476049, COSV99067042; called by muse, varscan2
- PCYOX1 | c.76G>A p.E26K | Missense Mutation (SNP) | VAF 6/16 reads (38%) | SIFT tolerated (0.5); PolyPhen benign (0); catalogued as rs751585124, COSV52476064, COSV99067040; called by muse, varscan2
- PDE6A | c.1467G>C p.E489D | Missense Mutation (SNP) | VAF 12/50 reads (24%) | SIFT tolerated (0.3); PolyPhen benign (0.001); catalogued as COSV54926267; called by muse, mutect2, varscan2
- PDE9A | c.1280G>T p.R427I | Missense Mutation (SNP) | VAF 3/10 reads (30%) | SIFT deleterious (0); PolyPhen benign (0.1); catalogued as rs781169820, COSV52324617; called by muse, mutect2
- PDSS1 | c.601G>A p.E201K | Missense Mutation (SNP) | VAF 5/31 reads (16%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.593); catalogued as COSV66058723; called by muse, mutect2, varscan2
- PEAK1 | c.787G>A p.E263K | Missense Mutation (SNP) | VAF 8/19 reads (42%) | SIFT deleterious (0); PolyPhen possibly damaging (0.76); catalogued as COSV56933480; called by muse, mutect2, varscan2
- PGBD4 | c.281G>A p.R94K | Missense Mutation (SNP) | VAF 10/29 reads (34%) | SIFT tolerated (0.14); PolyPhen benign (0.043); catalogued as rs35595072, COSV56627434; called by muse, mutect2, varscan2
- PHEX | c.847G>A p.E283K | Missense Mutation (SNP) | VAF 8/34 reads (24%) | SIFT tolerated (0.17); PolyPhen benign (0.056); catalogued as COSV65074828; called by muse, mutect2, varscan2
- PHKB | c.3031G>A p.E1011K | Missense Mutation (SNP) | VAF 8/30 reads (27%) | SIFT tolerated (0.12); PolyPhen benign (0.358); catalogued as COSV100065658; called by muse, mutect2
- PHLDB2 | c.3331C>T p.R1111C (on ENST00000393925 / NM_001134439.2; = p.R1068C on NM_145753.2) | Missense Mutation (SNP) | VAF 13/31 reads (42%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.626); catalogued as rs146545101; called by muse, mutect2, varscan2
- PI4KA | c.5067G>A p.W1689* | Nonsense Mutation (SNP) | VAF 10/24 reads (42%) | catalogued as COSV55408553; called by muse, mutect2, varscan2
- PICALM | c.632A>G p.Y211C | Missense Mutation (SNP) | VAF 18/41 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.92); catalogued as COSV62670185; called by muse, mutect2, varscan2
- PIK3C2A | c.158G>A p.R53K | Missense Mutation (SNP) | VAF 19/48 reads (40%) | SIFT tolerated, low confidence (0.95); PolyPhen benign (0.01); catalogued as COSV56401749; called by muse, mutect2, varscan2
- PKHD1L1 | c.6121G>A p.D2041N | Missense Mutation (SNP) | VAF 10/32 reads (31%) | SIFT tolerated (0.28); PolyPhen benign (0.006); catalogued as COSV65740933; called by muse, mutect2, varscan2
- PKHD1L1 | c.11986G>C p.E3996Q | Missense Mutation (SNP) | VAF 8/29 reads (28%) | SIFT tolerated (0.1); PolyPhen benign (0.11); catalogued as COSV65740937; called by muse, mutect2, varscan2
- PLCH1 | c.3418G>A p.G1140S (on ENST00000340059 / NM_001130960.2; = p.G1132S on NM_014996.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 8/34 reads (24%) | SIFT tolerated, low confidence (0.57); PolyPhen benign (0.251); catalogued as COSV58192699; called by muse, mutect2, varscan2
- PLCH1 | c.2924G>A p.R975K (on ENST00000340059 / NM_001130960.2; = p.R967K on NM_014996.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 5/43 reads (12%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as rs1476820566, COSV58192716; called by muse, mutect2
- PLEC | c.1938G>C p.Q646H (on ENST00000322810 / NM_201380.4; = p.Q536H on NM_000445.5) | Missense Mutation (SNP) | VAF 18/47 reads (38%) | SIFT tolerated (0.08); PolyPhen benign (0); catalogued as COSV59623978; called by muse, mutect2
- PLEKHA8 | c.1165G>A p.E389K | Missense Mutation (SNP) | VAF 6/28 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); catalogued as COSV51648687, COSV99033767; called by muse, mutect2, varscan2
- PLPP3 | c.531G>C p.Q177H | Missense Mutation (SNP) | VAF 21/76 reads (28%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.796); catalogued as COSV64839143; called by muse, mutect2, varscan2
- PLVAP | c.1191G>A p.M397I | Missense Mutation (SNP) | VAF 15/51 reads (29%) | SIFT tolerated (0.41); PolyPhen benign (0); catalogued as rs768106935, COSV53084416; called by muse, mutect2, varscan2
- PLXNA2 | c.358G>A p.D120N | Missense Mutation (SNP) | VAF 24/93 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs1411615797, COSV65439675; called by muse, mutect2, varscan2
- PLXNB1 | c.3181G>A p.E1061K | Missense Mutation (SNP) | VAF 14/59 reads (24%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.476); catalogued as COSV56486893, COSV56488598; called by muse, mutect2, varscan2
- PML | c.502G>A p.E168K | Missense Mutation (SNP) | VAF 8/30 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.606); catalogued as COSV51444880; called by muse, mutect2
- PNRC1 | c.217C>T p.R73C | Missense Mutation (SNP) | VAF 6/29 reads (21%) | SIFT tolerated, low confidence (0.1); PolyPhen possibly damaging (0.736); catalogued as COSV100260066, COSV60139463; called by muse, mutect2
- POLD3 | c.986C>G p.S329C | Missense Mutation (SNP) | VAF 12/39 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV99737642; called by muse, mutect2, varscan2
- POU1F1 | c.321C>G p.F107L | Missense Mutation (SNP) | VAF 11/56 reads (20%) | SIFT tolerated, low confidence (0.27); PolyPhen probably damaging (0.914); catalogued as COSV60155514, COSV60157295; called by muse, mutect2, varscan2
- PPFIA3 | c.504G>C p.E168D | Missense Mutation (SNP) | VAF 7/37 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV61950840; called by muse, mutect2, varscan2
- PRDM2 | c.1144C>T p.H382Y | Missense Mutation (SNP) | VAF 15/64 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52445095; called by muse, mutect2, varscan2
- PRKD2 | c.1287C>A p.F429L | Missense Mutation (SNP) | VAF 11/41 reads (27%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.965); catalogued as COSV52185781, COSV52190640; called by muse, mutect2, varscan2
- PRKDC | c.5098A>G p.T1700A | Missense Mutation (SNP) | VAF 8/16 reads (50%) | SIFT tolerated (0.16); PolyPhen benign (0.254); catalogued as COSV58049048; called by muse, mutect2, varscan2
- PRMT6 | c.245G>A p.R82Q | Missense Mutation (SNP) | VAF 7/31 reads (23%) | SIFT tolerated (0.34); PolyPhen benign (0.121); catalogued as COSV63655300; called by muse, mutect2, varscan2
- PRPF31 | c.725C>T p.S242F | Missense Mutation (SNP) | VAF 18/115 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs1315027213, COSV58084990; called by muse, mutect2, varscan2
- PSG4 | c.154C>T p.L52F | Missense Mutation (SNP) | VAF 45/110 reads (41%) | SIFT deleterious (0); PolyPhen benign (0.305); catalogued as COSV54934919; called by muse, mutect2, varscan2
- PSMB8 | c.304C>T p.R102W (on ENST00000374882 / NM_148919.4; = p.R98W on NM_004159.5) | Missense Mutation (SNP) | VAF 10/19 reads (53%) | SIFT deleterious (0); PolyPhen possibly damaging (0.447); catalogued as rs1402857650, COSV62754215; called by muse, mutect2, varscan2
- PTPRN | c.181C>T p.Q61* | Nonsense Mutation (SNP) | VAF 16/40 reads (40%) | catalogued as COSV55347037; called by muse, mutect2, varscan2
- PTPRS | c.493G>C p.E165Q | Missense Mutation (SNP) | VAF 10/128 reads (8%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.743); catalogued as COSV99509266; called by muse, mutect2
- PWWP3A | c.10G>C p.D4H (on ENST00000627377; = p.D3H on NM_032853.5 and 7 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 11/81 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV60901755; called by muse, mutect2, varscan2
- RAB11FIP1 | c.1724C>G p.S575C | Missense Mutation (SNP) | VAF 13/42 reads (31%) | SIFT deleterious (0.05); PolyPhen benign (0); catalogued as rs1425906453, COSV54759247; called by muse, mutect2, varscan2
- RABEP1 | c.1060C>G p.Q354E | Missense Mutation (SNP) | VAF 17/50 reads (34%) | SIFT tolerated (0.6); PolyPhen benign (0.001); catalogued as COSV52584372; called by muse, mutect2, varscan2
- RAD17 | c.637G>A p.G213R (on ENST00000380774 / NM_133339.2; = p.G202R on NM_002873.1) | Missense Mutation (SNP) | VAF 15/47 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV51457237; called by muse, mutect2, varscan2
- RALGAPA2 | c.4898G>C p.R1633T | Missense Mutation (SNP) | VAF 8/28 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV52494064; called by muse, mutect2, varscan2
- RANBP3 | c.178G>T p.E60* | Nonsense Mutation (SNP) | VAF 16/48 reads (33%) | catalogued as rs754068129, COSV99222164; called by muse, mutect2, varscan2
- RAP2C | c.203G>C p.R68T | Missense Mutation (SNP) | VAF 12/60 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV61683299; called by muse, varscan2
- RAPGEF4 | c.1834G>A p.D612N | Missense Mutation (SNP) | VAF 11/28 reads (39%) | SIFT deleterious (0.04); PolyPhen benign (0.007); catalogued as COSV51384062; called by muse, mutect2, varscan2
- RASGRP4 | c.62G>A p.R21Q | Missense Mutation (SNP) | VAF 41/173 reads (24%) | SIFT tolerated (0.11); PolyPhen benign (0.003); catalogued as rs376854073, COSV53094097; called by muse, mutect2, varscan2
- RB1 | c.1901C>A p.S634* | Nonsense Mutation (SNP) | VAF 13/43 reads (30%) | catalogued as CM961233, COSV57296525, COSV57302654; called by muse, mutect2, varscan2
- RB1CC1 | c.2062G>A p.E688K | Missense Mutation (SNP) | VAF 3/12 reads (25%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.985); catalogued as COSV50245717; called by muse, mutect2
- RBL1 | c.2244G>T p.K748N | Missense Mutation (SNP) | VAF 41/131 reads (31%) | SIFT tolerated (0.44); PolyPhen benign (0.013); catalogued as COSV60329394; called by muse, mutect2, varscan2
- RBL1 | c.1166C>T p.S389L | Missense Mutation (SNP) | VAF 22/55 reads (40%) | SIFT tolerated (0.1); PolyPhen benign (0.118); catalogued as rs771087993, COSV60329865; called by muse, mutect2, varscan2
- RBM10 | c.1592C>T p.S531L | Missense Mutation (SNP) | VAF 14/47 reads (30%) | SIFT tolerated (0.05); PolyPhen benign (0.281); catalogued as COSV61308605, COSV61310981; called by muse, mutect2, varscan2
- RBM4B | c.143C>T p.A48V | Missense Mutation (SNP) | VAF 11/105 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as COSV59496680; called by muse, mutect2, varscan2
- RBSN | c.1046C>T p.P349L | Missense Mutation (SNP) | VAF 20/84 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.982); catalogued as COSV99515031; called by muse, mutect2, varscan2
- REPS2 | c.1367G>A p.R456K | Missense Mutation (SNP) | VAF 6/40 reads (15%) | SIFT tolerated (0.28); PolyPhen possibly damaging (0.6); catalogued as COSV58180897; called by muse, mutect2, varscan2
- REV1 | c.1609C>T p.Q537* | Nonsense Mutation (SNP) | VAF 13/40 reads (33%) | catalogued as COSV51483831; called by muse, mutect2, varscan2
- RHOH | c.536G>C p.R179T | Missense Mutation (SNP) | VAF 7/15 reads (47%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.95); catalogued as COSV101110556, COSV67805376; called by muse, mutect2, varscan2
- RIF1 | c.391G>A p.E131K | Missense Mutation (SNP) | VAF 21/64 reads (33%) | SIFT deleterious (0.01); PolyPhen benign (0.069); catalogued as COSV54615401; called by muse, mutect2, varscan2
- RIPPLY3 | c.352G>A p.E118K | Missense Mutation (SNP) | VAF 10/24 reads (42%) | SIFT deleterious (0.03); PolyPhen benign (0.08); catalogued as COSV61566634; called by muse, mutect2, varscan2
- RIT1 | c.514G>A p.D172N | Missense Mutation (SNP) | VAF 14/87 reads (16%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.995); catalogued as COSV64171071; called by muse, mutect2, varscan2
- RNF17 | c.107G>A p.G36E | Missense Mutation (SNP) | VAF 14/44 reads (32%) | SIFT tolerated, low confidence (0.13); PolyPhen possibly damaging (0.554); catalogued as COSV55038034; called by muse, mutect2, varscan2
- RP1 | c.5971C>T p.Q1991* | Nonsense Mutation (SNP) | VAF 7/26 reads (27%) | catalogued as COSV55114319, COSV55118960; called by muse, mutect2, varscan2
- RPGRIP1 | c.1112G>A p.R371Q | Missense Mutation (SNP) | VAF 16/38 reads (42%) | SIFT deleterious (0.02); PolyPhen benign (0.127); catalogued as rs980350108, COSV52844460, COSV52846680; called by muse, mutect2, varscan2
- RPGRIP1 | c.1486C>T p.Q496* | Nonsense Mutation (SNP) | VAF 29/75 reads (39%) | catalogued as COSV99250511; called by muse, mutect2, varscan2
- RPL7L1 | c.494G>C p.G165A | Missense Mutation (SNP) | VAF 6/27 reads (22%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.782); catalogued as COSV59034557; called by muse, mutect2, varscan2
- RPS19 | c.52C>G p.L18V | Missense Mutation (SNP) | VAF 19/67 reads (28%) | SIFT tolerated (0.13); PolyPhen benign (0.158); catalogued as COSV55743229; called by muse, mutect2, varscan2
- RPS5 | c.351C>G p.I117M | Missense Mutation (SNP) | VAF 23/106 reads (22%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.951); catalogued as COSV52190740; called by muse, mutect2, varscan2
- RSPH10B | c.2353G>C p.E785Q | Missense Mutation (SNP) | VAF 37/234 reads (16%) | SIFT deleterious (0.04); PolyPhen benign (0.007); catalogued as COSV100382878, COSV58073751; called by muse, mutect2, varscan2
- RSPH10B2 | c.2353G>C p.E785Q | Missense Mutation (SNP) | VAF 9/16 reads (56%) | SIFT deleterious (0.04); PolyPhen benign (0.007); catalogued as COSV51868652; called by mutect2, varscan2
- SAMSN1 | c.910G>A p.E304K | Missense Mutation (SNP) | VAF 6/74 reads (8%) | SIFT deleterious (0.01); PolyPhen benign (0.009); catalogued as COSV99580730; called by muse, mutect2
- SATB1 | c.1392C>G p.I464M | Missense Mutation (SNP) | VAF 17/71 reads (24%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.454); catalogued as COSV58668541; called by muse, mutect2, varscan2
- SBNO1 | c.2665G>A p.E889K (on ENST00000420886; = p.E888K on NM_018183.5) | Missense Mutation (SNP) | VAF 15/64 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV57338665; called by muse, mutect2, varscan2
- SCN1A | c.5103C>G p.I1701M (on ENST00000303395 / NM_001202435.3; = p.I1690M on NM_006920.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 24/76 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV57666215, COSV57673264; called by muse, mutect2, varscan2
- SCO2 | c.752C>A p.S251* | Nonsense Mutation (SNP) | VAF 27/68 reads (40%) | catalogued as COSV52687336; called by muse, mutect2, varscan2
- SDK2 | c.5577C>G p.I1859M | Missense Mutation (SNP) | VAF 6/40 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.936); catalogued as COSV66184341; called by muse, mutect2, varscan2
- SEC16A | c.445G>A p.E149K | Missense Mutation (SNP) | VAF 12/29 reads (41%) | SIFT tolerated (0.13); PolyPhen benign (0.281); catalogued as COSV99256379; called by muse, mutect2, varscan2
- SEC31A | c.1015G>C p.D339H | Missense Mutation (SNP) | VAF 6/23 reads (26%) | SIFT deleterious (0); PolyPhen benign (0.396); catalogued as COSV52343839; called by muse, mutect2, varscan2
- SEMA3E | c.1780G>A p.E594K | Missense Mutation (SNP) | VAF 28/71 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.874); catalogued as COSV57085628; called by muse, mutect2, varscan2
- SEPTIN14 | c.43G>A p.D15N | Missense Mutation (SNP) | VAF 9/35 reads (26%) | SIFT tolerated (0.31); PolyPhen benign (0.003); catalogued as COSV66427116; called by muse, mutect2, varscan2
- SERPINA9 | c.565G>A p.D189N | Missense Mutation (SNP) | VAF 9/50 reads (18%) | SIFT tolerated (0.6); PolyPhen benign (0.097); catalogued as COSV54074102; called by muse, mutect2, varscan2
- SETD5 | c.3443C>T p.S1148F | Missense Mutation (SNP) | VAF 13/59 reads (22%) | SIFT tolerated (0.29); PolyPhen benign (0.11); catalogued as COSV56709502; called by muse, mutect2, varscan2
- SF3A3 | c.816G>C p.L272F | Missense Mutation (SNP) | VAF 6/39 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.783); catalogued as COSV65955734; called by muse, mutect2
- SH3TC1 | c.178G>T p.A60S | Missense Mutation (SNP) | VAF 12/33 reads (36%) | SIFT tolerated (0.16); PolyPhen benign (0.015); catalogued as COSV55283190; called by muse, mutect2, varscan2
- SHROOM4 | c.3016G>A p.E1006K | Missense Mutation (SNP) | VAF 8/48 reads (17%) | SIFT tolerated (0.08); PolyPhen benign (0.196); catalogued as COSV56783504, COSV56787533; called by muse, mutect2
- SKI | c.1435G>A p.D479N | Missense Mutation (SNP) | VAF 5/14 reads (36%) | SIFT tolerated (0.06); PolyPhen benign (0.011); catalogued as COSV66013289; called by muse, mutect2, varscan2
- SKOR1 | c.2497C>T p.P833S | Missense Mutation (SNP) | VAF 19/49 reads (39%) | SIFT tolerated (0.12); PolyPhen benign (0.108); catalogued as COSV58245054; called by muse, mutect2, varscan2
- SLA | c.37G>A p.E13K (on ENST00000338087 / NM_001045556.3; = p.E53K on NM_006748.4) | Missense Mutation (SNP) | VAF 34/100 reads (34%) | SIFT tolerated (0.19); PolyPhen benign (0.078); catalogued as rs376259266; called by muse, mutect2, varscan2
- SLC17A2 | c.848dup p.S284Qfs*24 | Frame Shift Ins (INS) | VAF 12/57 reads (21%) | catalogued as rs1037820299; called by mutect2, pindel, varscan2
- SLC1A6 | c.436G>A p.G146S | Missense Mutation (SNP) | VAF 9/42 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as rs568446140, COSV55669540; called by muse, mutect2, varscan2
- SLC25A35 | c.268G>A p.G90R | Missense Mutation (SNP) | VAF 18/33 reads (55%) | SIFT tolerated (0.37); PolyPhen benign (0); catalogued as COSV56839257; called by muse, mutect2, varscan2
- SLC25A47 | c.723C>G p.I241M | Missense Mutation (SNP) | VAF 32/73 reads (44%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.98); catalogued as rs747099355, COSV59925049; called by muse, mutect2, varscan2
- SLC38A9 | c.803C>G p.S268C | Missense Mutation (SNP) | VAF 20/51 reads (39%) | SIFT tolerated (0.11); PolyPhen benign (0.43); catalogued as COSV59422791; called by muse, mutect2, varscan2
- SLC7A3 | c.1776G>C p.E592D | Missense Mutation (SNP) | VAF 25/97 reads (26%) | SIFT tolerated (0.23); PolyPhen benign (0.005); catalogued as COSV53227074; called by muse, mutect2, varscan2
- SMG1 | c.4456G>C p.E1486Q | Missense Mutation (SNP) | VAF 20/63 reads (32%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.979); catalogued as COSV67170636; called by muse, varscan2
- SMG1 | c.4348G>T p.E1450* | Nonsense Mutation (SNP) | VAF 13/41 reads (32%) | catalogued as COSV67170640; called by muse, mutect2, varscan2
- SMG8 | c.2782C>T p.Q928* | Nonsense Mutation (SNP) | VAF 30/67 reads (45%) | catalogued as COSV56284807; called by muse, mutect2, varscan2
- SMUG1 | c.85G>C p.E29Q | Missense Mutation (SNP) | VAF 4/17 reads (24%) | SIFT tolerated (0.19); PolyPhen benign (0.003); catalogued as COSV54539404; called by muse, mutect2, varscan2
- SNAPC5 | c.31G>A p.E11K | Missense Mutation (SNP) | VAF 37/102 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs1213938785, COSV57206784; called by muse, mutect2, varscan2
- SNED1 | c.3136G>A p.E1046K | Missense Mutation (SNP) | VAF 18/44 reads (41%) | SIFT tolerated (0.21); PolyPhen benign (0.401); catalogued as COSV60022061; called by muse, mutect2, varscan2
- SOGA3 | c.1366G>A p.E456K | Missense Mutation (SNP) | VAF 25/66 reads (38%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.593); catalogued as COSV64106127; called by muse, mutect2, varscan2
- SPA17 | c.175G>T p.E59* | Nonsense Mutation (SNP) | VAF 12/45 reads (27%) | catalogued as COSV57032212; called by muse, mutect2, varscan2
- SPAG7 | c.429G>C p.Q143H | Missense Mutation (SNP) | VAF 14/27 reads (52%) | SIFT tolerated (0.1); PolyPhen benign (0.254); catalogued as COSV52776906; called by muse, mutect2, varscan2
- SPEN | c.6778G>A p.E2260K | Missense Mutation (SNP) | VAF 9/44 reads (20%) | SIFT tolerated, low confidence (0.23); PolyPhen benign (0.006); catalogued as COSV65358832, COSV65366325, COSV65369513; called by muse, mutect2, varscan2
- SPG7 | c.976G>C p.D326H | Missense Mutation (SNP) | VAF 20/65 reads (31%) | SIFT tolerated (0.2); PolyPhen benign (0.125); catalogued as COSV51949346; called by muse, mutect2, varscan2
- SPIC | c.335G>A p.R112Q | Missense Mutation (SNP) | VAF 14/43 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs746088939, COSV54690815; called by muse, mutect2, varscan2
- SPICE1 | c.1561C>G p.L521V | Missense Mutation (SNP) | VAF 16/51 reads (31%) | SIFT tolerated (0.83); PolyPhen benign (0.006); catalogued as COSV55619764; called by muse, mutect2, varscan2
- SPICE1 | c.944C>T p.S315L | Missense Mutation (SNP) | VAF 9/26 reads (35%) | SIFT tolerated (0.8); PolyPhen benign (0.087); catalogued as COSV55619786; called by muse, mutect2, varscan2
- SPNS3 | c.686G>A p.R229Q | Missense Mutation (SNP) | VAF 20/50 reads (40%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.969); catalogued as rs764514399, COSV100336865; called by muse, mutect2, varscan2
- SPRED1 | c.1175C>T p.S392L | Missense Mutation (SNP) | VAF 21/58 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1345810751, COSV54438084; called by muse, mutect2, varscan2
- SPRTN | c.61G>A p.E21K | Missense Mutation (SNP) | VAF 23/91 reads (25%) | SIFT tolerated (0.51); PolyPhen benign (0.001); catalogued as COSV50477903; called by muse, mutect2, varscan2
- SRGAP1 | c.2332G>C p.E778Q | Missense Mutation (SNP) | VAF 21/73 reads (29%) | SIFT tolerated (0.15); PolyPhen benign (0.014); catalogued as COSV61896485; called by muse, mutect2, varscan2
- SSRP1 | c.867G>A p.M289I | Missense Mutation (SNP) | VAF 20/41 reads (49%) | SIFT tolerated (0.11); PolyPhen benign (0.014); catalogued as rs1336619542, COSV53479024; called by muse, mutect2, varscan2
- ST18 | c.177G>A p.M59I | Missense Mutation (SNP) | VAF 39/107 reads (36%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.968); catalogued as rs749300022, COSV52490439; called by muse, mutect2, varscan2
- STAB1 | c.3905C>G p.S1302C | Missense Mutation (SNP) | VAF 17/51 reads (33%) | SIFT deleterious (0.03); PolyPhen benign (0.415); catalogued as COSV58734546, COSV58735550; called by muse, mutect2, varscan2
- STARD8 | c.2767G>C p.V923L | Missense Mutation (SNP) | VAF 13/63 reads (21%) | SIFT tolerated (0.11); PolyPhen benign (0.026); catalogued as COSV52924477; called by muse, mutect2, varscan2
- SUGP2 | c.574G>C p.D192H | Missense Mutation (SNP) | VAF 8/35 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); catalogued as COSV58257233; called by muse, mutect2, varscan2
- SULT1B1 | c.699G>A p.M233I | Missense Mutation (SNP) | VAF 20/52 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV60207300; called by muse, mutect2, varscan2
- SUN5 | c.799C>T p.Q267* | Nonsense Mutation (SNP) | VAF 21/77 reads (27%) | catalogued as COSV62180733; called by muse, mutect2, varscan2
- SVEP1 | c.4420G>A p.D1474N | Missense Mutation (SNP) | VAF 10/32 reads (31%) | SIFT deleterious (0.02); PolyPhen benign (0.243); catalogued as COSV57033612; called by muse, mutect2, varscan2
- SWT1 | c.146C>T p.S49L | Missense Mutation (SNP) | VAF 6/31 reads (19%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.193); catalogued as COSV62254279; called by muse, mutect2
- SYBU | c.1327G>A p.D443N (on ENST00000276646 / NM_001099754.2; = p.D442N on NM_017786.6) | Missense Mutation (SNP) | VAF 17/43 reads (40%) | SIFT deleterious (0); PolyPhen benign (0.084); catalogued as rs772224988, COSV52616398; called by muse, mutect2, varscan2
- SYNE1 | c.4427C>T p.S1476L (on ENST00000367255 / NM_182961.4; = p.S1483L on NM_033071.3) | Missense Mutation (SNP) | VAF 9/25 reads (36%) | SIFT deleterious (0); PolyPhen benign (0.031); catalogued as rs768845270, COSV54953577; called by muse, mutect2, varscan2
- TACC2 | c.6038T>C p.F2013S (on ENST00000334433; = p.F91S on NM_006997.4) | Missense Mutation (SNP) | VAF 14/37 reads (38%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.845); catalogued as COSV53279498; called by muse, mutect2, varscan2
- TADA3 | c.1104G>A p.L368= | Splice Region (SNP) | VAF 8/34 reads (24%) | catalogued as COSV57332923; called by muse, mutect2, varscan2
- TARS3 | c.2242C>G p.Q748E | Missense Mutation (SNP) | VAF 4/34 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as rs1324721412, COSV60107838; called by muse, mutect2, varscan2
- TBC1D10B | c.2424C>G p.F808L | Missense Mutation (SNP) | VAF 16/50 reads (32%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.956); catalogued as COSV59768503; called by muse, varscan2
- TCF25 | c.428C>T p.S143L | Missense Mutation (SNP) | VAF 16/42 reads (38%) | SIFT tolerated (0.32); PolyPhen benign (0); catalogued as rs766179873, COSV54526302; called by muse, mutect2, varscan2
- TCTEX1D2 | c.49G>A p.E17K | Missense Mutation (SNP) | VAF 30/83 reads (36%) | SIFT tolerated (0.05); PolyPhen benign (0.081); catalogued as COSV57488211, COSV57489713; called by muse, mutect2, varscan2
- TENM2 | c.7528G>A p.E2510K (on ENST00000518659 / NM_001122679.2; = p.E2271K on NM_001080428.3) | Missense Mutation (SNP) | VAF 17/68 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV69127466; called by muse, mutect2, varscan2
- TENT2 | c.1234C>T p.R412C | Missense Mutation (SNP) | VAF 14/41 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs759971099, COSV57136160; called by muse, mutect2, varscan2
- TERF1 | c.809G>A p.R270K | Missense Mutation (SNP) | VAF 16/39 reads (41%) | SIFT tolerated (0.39); PolyPhen possibly damaging (0.891); catalogued as COSV52577530; called by muse, mutect2, varscan2
- TERF1 | c.810A>T p.R270S | Missense Mutation (SNP) | VAF 16/39 reads (41%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.927); catalogued as COSV52577552; called by muse, mutect2, varscan2
- THAP7 | c.392G>A p.R131Q | Missense Mutation (SNP) | VAF 21/39 reads (54%) | SIFT tolerated (0.69); PolyPhen benign (0); catalogued as rs755408769, COSV53145783, COSV99301459; called by muse, mutect2, varscan2
- THOC2 | c.25C>T p.P9S | Missense Mutation (SNP) | VAF 6/64 reads (9%) | SIFT tolerated (0.44); PolyPhen benign (0.012); catalogued as rs1249742378, COSV99832821; called by muse, varscan2
- THSD7B | c.4175G>A p.R1392K (on ENST00000272643; = p.R1390K on NM_001316349.2) | Missense Mutation (SNP) | VAF 6/28 reads (21%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.983); catalogued as COSV55673520; called by muse, mutect2, varscan2
- TIE1 | c.2630C>G p.S877C | Missense Mutation (SNP) | VAF 5/22 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as COSV65249202; called by muse, mutect2, varscan2
- TIGD6 | c.826G>A p.E276K | Missense Mutation (SNP) | VAF 14/37 reads (38%) | SIFT tolerated (1); PolyPhen possibly damaging (0.448); catalogued as COSV57060817; called by muse, mutect2, varscan2
- TLK2 | c.857G>C p.R286T | Missense Mutation (SNP) | VAF 19/63 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV58298862; called by muse, mutect2, varscan2
- TMC4 | c.2063G>A p.R688K (on ENST00000617472 / NM_001145303.3; = p.R682K on NM_144686.4) | Missense Mutation (SNP) | VAF 11/33 reads (33%) | SIFT deleterious (0); PolyPhen benign (0.113); catalogued as COSV55362094; called by muse, mutect2
- TMC4 | c.614C>T p.S205L (on ENST00000617472 / NM_001145303.3; = p.S199L on NM_144686.4) | Missense Mutation (SNP) | VAF 20/50 reads (40%) | SIFT tolerated (0.2); PolyPhen benign (0.046); catalogued as rs779701401, COSV55475199; called by muse, mutect2, varscan2
- TMEM115 | c.11C>T p.A4V | Missense Mutation (SNP) | VAF 7/17 reads (41%) | SIFT tolerated (0.32); PolyPhen benign (0.017); catalogued as COSV51704436, COSV51704543; called by muse, mutect2, varscan2
- TMEM168 | c.1567G>A p.D523N | Missense Mutation (SNP) | VAF 14/38 reads (37%) | SIFT tolerated (0.22); PolyPhen benign (0.121); catalogued as COSV57180220; called by muse, mutect2, varscan2
- TMEM183A | c.656C>T p.S219F | Missense Mutation (SNP) | VAF 39/113 reads (35%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.814); catalogued as rs759000597, COSV65887705; called by muse, mutect2, varscan2
- TMEM8B | c.328G>A p.E110K | Missense Mutation (SNP) | VAF 22/61 reads (36%) | SIFT tolerated (0.47); PolyPhen benign (0.012); catalogued as COSV65076119; called by muse, mutect2, varscan2
- TNFSF10 | c.279G>C p.L93F | Missense Mutation (SNP) | VAF 15/40 reads (38%) | SIFT tolerated (0.49); PolyPhen probably damaging (0.963); catalogued as COSV53842986; called by muse, mutect2, varscan2
- TOGARAM2 | c.1924G>A p.E642K | Missense Mutation (SNP) | VAF 12/40 reads (30%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.589); catalogued as COSV101090895; called by muse, mutect2, varscan2
- TP53 | c.957G>C p.K319N | Missense Mutation (SNP) | VAF 29/65 reads (45%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.996); catalogued as COSV52794415, COSV52825630, COSV52843306, COSV53224496; called by muse, varscan2
- TP53 | c.861G>C p.E287D | Missense Mutation (SNP) | VAF 16/42 reads (38%) | SIFT tolerated (0.24); PolyPhen benign (0.011); catalogued as rs748891343, COSV52684280, COSV52840253, COSV52883064, COSV99362734; ClinVar: uncertain significance; called by muse, varscan2
- TPO | c.1627C>T p.L543F | Missense Mutation (SNP) | VAF 12/34 reads (35%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.586); catalogued as COSV61099437; called by muse, mutect2, varscan2
- TPR | c.6382G>C p.D2128H | Missense Mutation (SNP) | VAF 4/45 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); catalogued as COSV100823666; called by muse, mutect2
- TRAF3IP3 | c.979G>C p.E327Q | Missense Mutation (SNP) | VAF 7/28 reads (25%) | SIFT tolerated (0.14); PolyPhen benign (0.05); catalogued as COSV50551915, COSV50559490; called by muse, mutect2, varscan2
- TRAF7 | c.1539G>C p.K513N | Missense Mutation (SNP) | VAF 8/25 reads (32%) | SIFT tolerated (0.3); PolyPhen probably damaging (0.958); catalogued as COSV58213726; called by muse, mutect2, varscan2
- TRAT1 | c.520C>G p.L174V | Missense Mutation (SNP) | VAF 18/58 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV55468032, COSV55469623; called by muse, mutect2, varscan2
- TRBC2 | c.319G>A p.D107N | Missense Mutation (SNP) | VAF 8/32 reads (25%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.872); catalogued as rs782558931; called by muse, varscan2
- TRIM68 | c.697G>A p.E233K | Missense Mutation (SNP) | VAF 12/61 reads (20%) | SIFT tolerated (1); PolyPhen benign (0.005); catalogued as rs972702760, COSV56168182; called by muse, mutect2, varscan2
- TRIM9 | c.52C>T p.R18W | Missense Mutation (SNP) | VAF 12/32 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.948); catalogued as rs573997618, COSV53615598; called by muse, mutect2, varscan2
- TRIO | c.601G>A p.E201K | Missense Mutation (SNP) | VAF 16/54 reads (30%) | SIFT deleterious (0); PolyPhen benign (0.245); catalogued as COSV60081544; called by muse, mutect2, varscan2
- TRO | c.1109C>T p.S370F | Missense Mutation (SNP) | VAF 14/57 reads (25%) | SIFT deleterious (0.01); PolyPhen benign (0.03); catalogued as COSV51500080; called by muse, mutect2, varscan2
- TRUB1 | c.245C>T p.S82L | Missense Mutation (SNP) | VAF 23/64 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV53929101; called by muse, mutect2, varscan2
- TSSC4 | c.707G>C p.G236A | Missense Mutation (SNP) | VAF 26/81 reads (32%) | SIFT tolerated (0.77); PolyPhen benign (0.115); catalogued as COSV50148337; called by muse, mutect2
- TTC6 | c.40C>T p.Q14* (on ENST00000267368; = p.Q1283* on NM_001310135.3) | Nonsense Mutation (SNP) | VAF 9/47 reads (19%) | catalogued as COSV57447717; called by muse, mutect2, varscan2
- TTN | c.35593G>A p.E11865K (on ENST00000591111; = p.E4441K on NM_003319.4) | Missense Mutation (SNP) | VAF 9/37 reads (24%) | PolyPhen benign (0.35); catalogued as COSV59983965, COSV60215753; called by muse, mutect2, varscan2
- TTN | c.33175G>A p.E11059K (on ENST00000591111; = p.E10132K on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 29/78 reads (37%) | PolyPhen benign (0.406); catalogued as COSV59983998; called by muse, mutect2, varscan2
- TXLNB | c.319G>A p.E107K | Missense Mutation (SNP) | VAF 37/93 reads (40%) | SIFT deleterious (0.04); PolyPhen benign (0.194); catalogued as rs74766867; called by muse, mutect2, varscan2
- UACA | c.1660G>A p.E554K | Missense Mutation (SNP) | VAF 10/56 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV59854915; called by muse, mutect2, varscan2
- UBASH3B | c.1057G>A p.E353K | Missense Mutation (SNP) | VAF 10/36 reads (28%) | SIFT tolerated (0.6); PolyPhen benign (0.031); catalogued as COSV52493129; called by muse, mutect2, varscan2
- UBQLN1 | c.914C>T p.S305F | Missense Mutation (SNP) | VAF 16/48 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.736); catalogued as COSV57406951, COSV57407386; called by muse, mutect2, varscan2
- UBR3 | c.4081C>T p.P1361S | Missense Mutation (SNP) | VAF 19/43 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV55847509; called by muse, mutect2, varscan2
- UGT3A2 | c.964C>T p.H322Y | Missense Mutation (SNP) | VAF 12/37 reads (32%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.74); catalogued as rs1008549031, COSV56929785; called by muse, mutect2, varscan2
- UNC13A | c.5013C>G p.I1671M | Missense Mutation (SNP) | VAF 11/57 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV53192749; called by muse, mutect2, varscan2
- USP11 | c.2464G>A p.E822K (on ENST00000218348; = p.E779K on NM_001371072.1) | Missense Mutation (SNP) | VAF 18/59 reads (31%) | SIFT tolerated (0.75); PolyPhen probably damaging (0.997); catalogued as COSV54473221; called by muse, mutect2, varscan2
- USP42 | c.287C>G p.S96C | Missense Mutation (SNP) | VAF 18/45 reads (40%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.887); catalogued as COSV60359180; called by muse, mutect2, varscan2
- USP48 | c.1357G>C p.E453Q | Missense Mutation (SNP) | VAF 24/137 reads (18%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.889); catalogued as COSV57608893; called by muse, mutect2, varscan2
- USP6 | c.4060G>C p.D1354H | Missense Mutation (SNP) | VAF 25/107 reads (23%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.992); catalogued as rs1473858705, COSV51479791, COSV51492226; called by muse, mutect2, varscan2
- USP6NL | c.1364C>T p.S455L | Missense Mutation (SNP) | VAF 19/52 reads (37%) | SIFT tolerated (0.29); PolyPhen benign (0.001); catalogued as COSV53210500, COSV53212358; called by muse, mutect2, varscan2
- UTRN | c.8493C>T p.I2831= | Splice Region (SNP) | VAF 14/55 reads (25%) | catalogued as COSV62308807; called by muse, mutect2, varscan2
- VMP1 | c.814G>C p.D272H | Missense Mutation (SNP) | VAF 3/47 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV51866451, COSV99229990; called by muse, mutect2
- VN1R1 | c.690G>A p.M230I | Missense Mutation (SNP) | VAF 32/81 reads (40%) | SIFT tolerated (0.79); PolyPhen benign (0.058); catalogued as COSV58090882; called by muse, mutect2, varscan2
- VPS16 | c.533C>G p.S178C | Missense Mutation (SNP) | VAF 22/83 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as COSV66793878; called by muse, mutect2, varscan2
- VPS18 | c.1796C>T p.S599L | Missense Mutation (SNP) | VAF 7/21 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.459); catalogued as COSV55029647; called by muse, mutect2, varscan2
- VPS4A | c.441C>G p.I147M | Missense Mutation (SNP) | VAF 13/60 reads (22%) | SIFT tolerated (0.09); PolyPhen benign (0.097); catalogued as COSV54750516; called by muse, mutect2, varscan2
- VPS9D1 | c.154G>C p.E52Q | Missense Mutation (SNP) | VAF 15/67 reads (22%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.69); catalogued as rs1452887356, COSV57067320; called by muse, mutect2, varscan2
- VWA8 | c.5419G>C p.E1807Q | Missense Mutation (SNP) | VAF 11/27 reads (41%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as COSV64995319; called by muse, mutect2, varscan2
- VWF | c.6751G>C p.E2251Q | Missense Mutation (SNP) | VAF 3/44 reads (7%) | SIFT deleterious (0.04); PolyPhen benign (0.301); catalogued as COSV99778125; called by muse, mutect2
- WASHC4 | c.950G>A p.G317E | Missense Mutation (SNP) | VAF 13/41 reads (32%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.744); catalogued as COSV59889188; called by muse, mutect2, varscan2
- WASL | c.1058C>G p.S353* | Nonsense Mutation (SNP) | VAF 27/93 reads (29%) | catalogued as COSV56133155; called by muse, mutect2, varscan2
- WBP2NL | c.836G>A p.G279E | Missense Mutation (SNP) | VAF 17/40 reads (43%) | SIFT tolerated, low confidence (0.29); PolyPhen benign (0.007); catalogued as rs1304990180, COSV60919104; called by muse, mutect2, varscan2
- WDR41 | c.877G>A p.E293K | Missense Mutation (SNP) | VAF 14/44 reads (32%) | SIFT tolerated (0.33); PolyPhen benign (0.214); catalogued as rs990405551, COSV56998355; called by muse, mutect2, varscan2
- WDR44 | c.868A>G p.S290G | Missense Mutation (SNP) | VAF 16/54 reads (30%) | SIFT tolerated (0.19); PolyPhen benign (0); catalogued as COSV54162366, COSV54171266; called by muse, mutect2, varscan2
- WDR47 | c.2563C>T p.H855Y (on ENST00000369962 / NM_001142551.2; = p.H856Y on NM_014969.5) | Missense Mutation (SNP) | VAF 4/25 reads (16%) | SIFT tolerated (1); PolyPhen benign (0.372); catalogued as rs780952000, COSV63057539; called by muse, mutect2, varscan2
- WDR6 | c.1396G>C p.E466Q | Missense Mutation (SNP) | VAF 7/45 reads (16%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.806); catalogued as rs1488521264, COSV58244645; called by muse, mutect2, varscan2
- WWC1 | c.1675G>A p.D559N | Missense Mutation (SNP) | VAF 12/35 reads (34%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.864); catalogued as COSV54649320; called by muse, mutect2, varscan2
- XIRP2 | c.616G>A p.D206N (on ENST00000628543; = p.D381N on NM_152381.6) | Missense Mutation (SNP) | VAF 3/20 reads (15%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.529); catalogued as COSV54693031, COSV99739645; called by muse, mutect2
- XPNPEP2 | c.1306G>A p.E436K | Missense Mutation (SNP) | VAF 6/48 reads (13%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.859); catalogued as COSV100941413; called by muse, mutect2
- XRN1 | c.3061G>C p.E1021Q | Missense Mutation (SNP) | VAF 6/71 reads (8%) | SIFT tolerated (0.23); PolyPhen benign (0.029); catalogued as COSV53811804, COSV99377309; called by muse, mutect2
- YEATS2 | c.1773C>G p.I591M | Missense Mutation (SNP) | VAF 6/92 reads (7%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.994); catalogued as COSV100527501, COSV59372099; called by muse, mutect2
- ZBTB21 | c.2149G>C p.E717Q | Missense Mutation (SNP) | VAF 10/43 reads (23%) | SIFT tolerated (0.53); PolyPhen benign (0.063); catalogued as COSV60403718; called by muse, varscan2
- ZBTB37 | c.451G>A p.E151K | Missense Mutation (SNP) | VAF 7/28 reads (25%) | SIFT tolerated (0.5); PolyPhen benign (0.011); catalogued as COSV62931963; called by muse, mutect2, varscan2
- ZBTB41 | c.2263C>T p.P755S | Missense Mutation (SNP) | VAF 39/115 reads (34%) | SIFT tolerated (0.2); PolyPhen benign (0); catalogued as COSV66358992; called by muse, mutect2, varscan2
- ZC3H18 | c.2680C>T p.P894S | Missense Mutation (SNP) | VAF 5/19 reads (26%) | SIFT tolerated, low confidence (0.05); PolyPhen probably damaging (0.998); catalogued as COSV56324001; called by muse, varscan2
- ZNF180 | c.538C>T p.Q180* | Nonsense Mutation (SNP) | VAF 17/56 reads (30%) | catalogued as rs768704889, COSV55420672, COSV55420750; called by muse, mutect2, varscan2
- ZNF274 | c.604G>A p.E202K (on ENST00000610905; = p.E97K on NM_016324.3) | Missense Mutation (SNP) | VAF 7/63 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV58763892; called by muse, mutect2, varscan2
- ZNF292 | c.1303G>A p.V435I | Missense Mutation (SNP) | VAF 12/35 reads (34%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.96); catalogued as COSV60537754; called by muse, mutect2, varscan2
- ZNF302 | c.544G>C p.V182L (on ENST00000627982; = p.V103L on NM_018443.3 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 14/44 reads (32%) | SIFT tolerated (0.98); PolyPhen benign (0.007); catalogued as rs1235633362, COSV71063455; called by muse, mutect2, varscan2
- ZNF347 | c.1938C>G p.I646M | Missense Mutation (SNP) | VAF 29/87 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.745); catalogued as COSV100498153, COSV100498336; called by muse, mutect2, varscan2
- ZNF417 | c.1036C>G p.H346D | Missense Mutation (SNP) | VAF 19/119 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV56308033; called by muse, mutect2, varscan2
- ZNF429 | c.1534G>A p.E512K | Missense Mutation (SNP) | VAF 8/28 reads (29%) | SIFT tolerated (0.21); PolyPhen probably damaging (0.982); catalogued as COSV100642004, COSV61915610; called by muse, mutect2, varscan2
- ZNF471 | c.1009C>G p.Q337E | Missense Mutation (SNP) | VAF 7/24 reads (29%) | SIFT deleterious (0); PolyPhen benign (0.209); catalogued as COSV57290439; called by muse, mutect2, varscan2
- ZNF510 | c.1063C>T p.Q355* | Nonsense Mutation (SNP) | VAF 11/24 reads (46%) | catalogued as COSV56296900; called by muse, mutect2, varscan2
- ZNF519 | c.1519C>T p.Q507* | Nonsense Mutation (SNP) | VAF 9/17 reads (53%) | catalogued as COSV73913282, COSV73913298; called by muse, mutect2, varscan2
- ZNF519 | c.1429C>T p.Q477* | Nonsense Mutation (SNP) | VAF 16/29 reads (55%) | catalogued as COSV73913283; called by muse, mutect2, varscan2
- ZNF593 | c.90G>C p.E30D | Missense Mutation (SNP) | VAF 4/11 reads (36%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.621); catalogued as rs1380315691, COSV54631247; called by muse, mutect2, varscan2
- ZNF615 | c.1882G>A p.E628K | Missense Mutation (SNP) | VAF 7/46 reads (15%) | SIFT deleterious (0.05); PolyPhen benign (0.087); catalogued as COSV65032663; called by muse, mutect2, varscan2
- ZNF646 | c.4273C>G p.P1425A | Missense Mutation (SNP) | VAF 28/86 reads (33%) | SIFT tolerated (0.56); PolyPhen benign (0); catalogued as COSV54923728; called by muse, varscan2
- ZNF646 | c.4441C>G p.Q1481E | Missense Mutation (SNP) | VAF 23/55 reads (42%) | SIFT tolerated (0.31); PolyPhen benign (0.039); catalogued as COSV54923736, COSV99762115; called by muse, varscan2
- ZNF646 | c.5153C>G p.S1718C | Missense Mutation (SNP) | VAF 14/44 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); catalogued as COSV54923745; called by muse, mutect2, varscan2
- ZNF770 | c.1063C>T p.Q355* | Nonsense Mutation (SNP) | VAF 9/31 reads (29%) | catalogued as COSV62544159; called by muse, mutect2, varscan2
- ZNF8 | c.1434G>C p.Q478H | Missense Mutation (SNP) | VAF 10/46 reads (22%) | SIFT deleterious (0.02); PolyPhen benign (0.242); catalogued as COSV52187207; called by muse, mutect2, varscan2
- ZNF80 | c.773C>T p.S258F | Missense Mutation (SNP) | VAF 15/57 reads (26%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.518); catalogued as COSV57359826; called by muse, mutect2, varscan2
- ZNF804B | c.3700C>T p.H1234Y | Missense Mutation (SNP) | VAF 46/109 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.915); catalogued as COSV60823424; called by muse, mutect2, varscan2
- ZNF804B | c.3850C>T p.Q1284* | Nonsense Mutation (SNP) | VAF 41/90 reads (46%) | catalogued as rs771320201, COSV60823427; called by muse, mutect2, varscan2
- ZNF85 | c.266A>G p.E89G | Missense Mutation (SNP) | VAF 6/48 reads (13%) | SIFT deleterious (0.04); PolyPhen benign (0.07); catalogued as COSV56021415; called by muse, mutect2
- ZNF92 | c.341G>A p.R114K (on ENST00000328747 / NM_152626.4; = p.R45K on NM_007139.4) | Missense Mutation (SNP) | VAF 6/53 reads (11%) | SIFT tolerated (0.45); PolyPhen benign (0.013); catalogued as COSV60873792; called by muse, mutect2, varscan2
- ZNF93 | c.890C>A p.S297Y | Missense Mutation (SNP) | VAF 6/31 reads (19%) | SIFT tolerated (0.46); PolyPhen possibly damaging (0.894); catalogued as COSV59375017, COSV59375607; called by muse, mutect2, varscan2
- ZRANB1 | c.2012G>A p.R671Q | Missense Mutation (SNP) | VAF 14/42 reads (33%) | SIFT tolerated (0.34); PolyPhen benign (0.201); catalogued as rs774002081, COSV58333578; called by muse, mutect2, varscan2
- ZYG11B | c.91G>C p.E31Q | Missense Mutation (SNP) | VAF 16/47 reads (34%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.943); catalogued as COSV53751891; called by muse, mutect2, varscan2
- ZYG11B | c.1727C>T p.S576F | Missense Mutation (SNP) | VAF 3/22 reads (14%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.672); catalogued as COSV53751906; called by muse, mutect2
- CNTN3 | c.2731_2733del p.V911del | In Frame Del (DEL) | VAF 8/44 reads (18%) | called by pindel, varscan2
- FNIP2 | c.158_169del p.Q53_D56del | In Frame Del (DEL) | VAF 29/78 reads (37%) | called by mutect2, pindel, varscan2
- MAML2 | c.2414_2417delinsAA p.R805Kfs*24 | Frame Shift Del (DEL) | VAF 27/63 reads (43%) | called by pindel, varscan2*
- MYNN | c.439C>G p.L147V | Missense Mutation (SNP) | VAF 3/40 reads (8%) | SIFT tolerated (0.33); PolyPhen possibly damaging (0.899); called by muse, mutect2
- NCOA4 | c.1388C>T p.P463L | Missense Mutation (SNP) | VAF 12/39 reads (31%) | SIFT deleterious (0.02); PolyPhen benign (0.097); called by muse, mutect2, varscan2
- SF3A3 | c.646G>A p.E216K | Missense Mutation (SNP) | VAF 5/30 reads (17%) | SIFT tolerated (0.08); PolyPhen benign (0.01); called by muse, mutect2
- SMG1 | c.4462dup p.T1488Nfs*31 | Frame Shift Ins (INS) | VAF 17/67 reads (25%) | called by pindel, varscan2
- SPATA31A1 | c.967G>A p.D323N | Missense Mutation (SNP) | VAF 63/178 reads (35%) | SIFT tolerated (0.08); PolyPhen benign (0.421); called by muse, mutect2, varscan2
- AAK1 | c.693C>T p.V231= | Silent (SNP) | VAF 15/58 reads (26%) | catalogued as COSV101276012, COSV68643081; called by muse, mutect2, varscan2
- ABCA12 | c.7470G>A p.L2490= (on ENST00000272895 / NM_173076.3; = p.L2172= on NM_015657.3) | Silent (SNP) | VAF 6/23 reads (26%) | catalogued as COSV55954959; called by muse, mutect2, varscan2
- ABCA3 | c.3747C>T p.F1249= | Silent (SNP) | VAF 20/99 reads (20%) | catalogued as COSV100068070; called by muse, mutect2, varscan2
- ABCB8 | c.1743G>A p.V581= (on ENST00000297504 / NM_001282291.2; = p.V564= on NM_007188.5) | Silent (SNP) | VAF 6/20 reads (30%) | catalogued as COSV52503649; called by muse, mutect2, varscan2
- ABCC6 | c.4140C>G p.L1380= | Silent (SNP) | VAF 9/38 reads (24%) | catalogued as rs368258006, COSV52742997; called by muse, mutect2, varscan2
- ABHD10 | c.240C>T p.F80= | Silent (SNP) | VAF 15/67 reads (22%) | catalogued as COSV56324902; called by muse, mutect2, varscan2
- ACTN2 | c.2568G>A p.P856= | Silent (SNP) | VAF 14/62 reads (23%) | catalogued as rs149554430; ClinVar: uncertain significance / likely benign; called by muse, mutect2, varscan2
- ADCY8 | c.2571G>A p.L857= | Silent (SNP) | VAF 12/25 reads (48%) | catalogued as COSV53903461; called by muse, mutect2, varscan2
- AKR7A2 | c.660G>A p.L220= | Silent (SNP) | VAF 12/96 reads (13%) | catalogued as COSV52516054; called by muse, mutect2, varscan2
- ALAS2 | c.258G>A p.Q86= | Silent (SNP) | VAF 25/84 reads (30%) | catalogued as COSV100237999; called by muse, mutect2, varscan2
- ALS2 | c.1215G>A p.V405= | Silent (SNP) | VAF 13/47 reads (28%) | catalogued as COSV51886014, COSV99968963; called by muse, mutect2, varscan2
- AP3D1 | c.3381C>G p.V1127= | Silent (SNP) | VAF 12/50 reads (24%) | catalogued as COSV61426652, COSV61430303; called by muse, varscan2
- APOB | c.471G>A p.K157= | Silent (SNP) | VAF 25/53 reads (47%) | catalogued as COSV51931334; called by muse, mutect2, varscan2
- ARAP2 | c.780A>G p.P260= | Silent (SNP) | VAF 9/28 reads (32%) | catalogued as COSV58285182; called by muse, mutect2, varscan2
- ARFGEF2 | c.1677G>A p.L559= | Silent (SNP) | VAF 11/45 reads (24%) | catalogued as COSV100904410, COSV64211674; called by muse, mutect2, varscan2
- ARHGEF11 | c.2550G>A p.E850= | Silent (SNP) | VAF 14/70 reads (20%) | catalogued as COSV59353505; called by muse, mutect2, varscan2
- ARPC4 | c.15C>A p.L5= | Silent (SNP) | VAF 35/122 reads (29%) | catalogued as COSV99809343; called by muse, mutect2, varscan2
- ASTL | c.126C>G p.L42= | Silent (SNP) | VAF 20/50 reads (40%) | catalogued as COSV60903972; called by muse, mutect2, varscan2
- ATP2C1 | c.318C>T p.I106= | Silent (SNP) | VAF 20/68 reads (29%) | called by muse, mutect2
- ATRIP | c.2375G>A p.*792= (on ENST00000320211 / NM_130384.3; = p.*765= on NM_032166.4) | Silent (SNP) | VAF 10/46 reads (22%) | catalogued as COSV56496209; called by muse, mutect2, varscan2
- BAIAP3 | c.1161C>T p.I387= | Silent (SNP) | VAF 25/94 reads (27%) | catalogued as rs1308086756, COSV60979223; called by muse, varscan2
- BCORL1 | c.4152C>T p.L1384= | Silent (SNP) | VAF 21/66 reads (32%) | catalogued as COSV99498592; called by muse, mutect2, varscan2
- BRS3 | c.999G>C p.L333= | Silent (SNP) | VAF 18/70 reads (26%) | catalogued as COSV65710859; called by muse, mutect2, varscan2
- C19orf47 | c.678C>T p.I226= | Silent (SNP) | VAF 17/84 reads (20%) | catalogued as rs138091126, COSV63508597; called by muse, mutect2, varscan2
- CARD19 | c.105G>C p.L35= | Silent (SNP) | VAF 10/65 reads (15%) | catalogued as COSV64935906; called by muse, mutect2, varscan2
- CASD1 | c.1767G>A p.L589= | Silent (SNP) | VAF 8/104 reads (8%) | catalogued as COSV99802313; called by muse, mutect2
- CBLIF | c.207G>A p.L69= | Silent (SNP) | VAF 31/79 reads (39%) | catalogued as COSV57238522; called by muse, mutect2, varscan2
- CCR8 | c.300G>A p.V100= | Silent (SNP) | VAF 32/209 reads (15%) | catalogued as COSV58337042; called by muse, mutect2, varscan2
- CHST7 | c.267C>T p.L89= | Silent (SNP) | VAF 20/66 reads (30%) | catalogued as COSV52099640; called by muse, mutect2, varscan2
- CMIP | c.915G>A p.K305= (on ENST00000537098 / NM_198390.2; = p.K211= on NM_030629.3) | Silent (SNP) | VAF 12/66 reads (18%) | catalogued as COSV67697852; called by muse, mutect2, varscan2
- CMSS1 | c.372G>A p.K124= | Silent (SNP) | VAF 13/67 reads (19%) | catalogued as COSV101375482; called by muse, mutect2, varscan2
- CNOT1 | c.6273C>G p.L2091= | Silent (SNP) | VAF 16/74 reads (22%) | catalogued as COSV99799336; called by muse, mutect2, varscan2
- COL19A1 | c.2421G>A p.G807= | Silent (SNP) | VAF 23/42 reads (55%) | catalogued as COSV59568981; called by muse, mutect2, varscan2
- COL5A1 | c.5292C>T p.L1764= | Silent (SNP) | VAF 28/69 reads (41%) | catalogued as COSV100879578; called by muse, mutect2, varscan2
- COL9A3 | c.1032C>T p.S344= | Silent (SNP) | VAF 13/42 reads (31%) | catalogued as COSV59651853; called by muse, mutect2, varscan2
- CSE1L | c.993G>A p.K331= | Silent (SNP) | VAF 14/66 reads (21%) | catalogued as COSV53701159; called by muse, mutect2, varscan2
- CSMD3 | c.3660C>T p.I1220= (on ENST00000297405 / NM_001363185.1; = p.I1116= on NM_052900.3) | Silent (SNP) | VAF 16/39 reads (41%) | catalogued as COSV52091934, COSV52149804; called by muse, mutect2, varscan2
- CYP2A7 | c.354C>T p.F118= | Silent (SNP) | VAF 17/69 reads (25%) | catalogued as COSV52500006; called by muse, varscan2
- DCHS1 | c.5151C>T p.I1717= | Silent (SNP) | VAF 29/88 reads (33%) | catalogued as COSV55033889; called by muse, mutect2, varscan2
- DDIT4L | c.534G>A p.K178= | Silent (SNP) | VAF 9/19 reads (47%) | catalogued as COSV56767189; called by muse, mutect2, varscan2
- DDOST | c.66C>T p.T22= (on ENST00000415136; = p.T5= on NM_005216.5) | Silent (SNP) | VAF 10/31 reads (32%) | catalogued as rs1184493108, COSV56117396; called by muse, mutect2, varscan2
- DDR2 | c.2466C>T p.D822= | Silent (SNP) | VAF 14/46 reads (30%) | catalogued as COSV63370408; called by muse, mutect2, varscan2
- DNAH10 | c.9993C>T p.L3331= (on ENST00000409039; = p.L3270= on NM_207437.3) | Silent (SNP) | VAF 7/17 reads (41%) | catalogued as COSV101292011; called by muse, mutect2, varscan2
- DOCK4 | c.4896G>A p.P1632= | Silent (SNP) | VAF 13/28 reads (46%) | catalogued as rs1274497749, COSV70238413; called by muse, mutect2, varscan2
- DRC7 | c.1107G>C p.V369= | Silent (SNP) | VAF 13/172 reads (8%) | catalogued as COSV100395385; called by muse, mutect2
- DSG3 | c.1863C>A p.I621= | Silent (SNP) | VAF 8/27 reads (30%) | catalogued as rs753349276, COSV57125446, COSV99934426; called by muse, mutect2, varscan2
- ECT2L | c.1899G>A p.L633= | Silent (SNP) | VAF 17/58 reads (29%) | catalogued as COSV62883876; called by muse, mutect2, varscan2
- EGFR | c.2385C>T p.F795= | Silent (SNP) | VAF 19/45 reads (42%) | catalogued as rs375332959; called by muse, mutect2
- EHMT1 | c.33G>A p.A11= | Silent (SNP) | VAF 12/47 reads (26%) | catalogued as rs754740754, COSV58373581; ClinVar: likely benign; called by muse, mutect2, varscan2
- ELMO3 | c.54C>T p.L18= | Silent (SNP) | VAF 22/74 reads (30%) | catalogued as rs1394552393, COSV62606266; called by muse, mutect2, varscan2
- ELN | c.2262G>A p.R754= (on ENST00000320399 / NM_001278939.1; = p.R721= on NM_000501.4) | Silent (SNP) | VAF 4/32 reads (13%) | catalogued as COSV52709346; called by muse, mutect2
- FAM181A | c.84G>A p.A28= | Silent (SNP) | VAF 5/13 reads (38%) | catalogued as rs552387444, COSV50887857, COSV50890024; called by muse, mutect2, varscan2
- FAM20B | c.783G>A p.K261= | Silent (SNP) | VAF 13/54 reads (24%) | catalogued as COSV55379814; called by muse, mutect2, varscan2
- FAT4 | c.3657A>T p.I1219= | Silent (SNP) | VAF 10/28 reads (36%) | catalogued as COSV67884026; called by muse, mutect2, varscan2
- FCGBP | c.2499C>T p.V833= | Silent (SNP) | VAF 6/31 reads (19%) | called by muse, mutect2, varscan2
- FHOD3 | c.3903G>A p.L1301= (on ENST00000359247 / NM_001281739.3; = p.L1318= on NM_025135.5) | Silent (SNP) | VAF 25/48 reads (52%) | catalogued as rs1225205790, COSV99940270; called by muse, varscan2
- FRG2C | c.624G>A p.L208= | Silent (SNP) | VAF 23/161 reads (14%) | catalogued as rs1179508202; called by muse, mutect2, varscan2
- GEMIN8 | c.600G>A p.E200= | Silent (SNP) | VAF 23/94 reads (24%) | catalogued as COSV60550322, COSV60550902; called by muse, mutect2, varscan2
- GHR | c.1197C>T p.F399= | Silent (SNP) | VAF 17/37 reads (46%) | catalogued as COSV50109103; called by muse, mutect2, varscan2
- GLA | c.9G>A p.L3= | Silent (SNP) | VAF 8/27 reads (30%) | catalogued as COSV54508794; called by muse, mutect2, varscan2
- GLS | c.1932C>G p.V644= | Silent (SNP) | VAF 7/22 reads (32%) | catalogued as rs1367797471, COSV100289747; called by muse, mutect2, varscan2
- GLT8D2 | c.309G>C p.L103= | Silent (SNP) | VAF 4/24 reads (17%) | catalogued as COSV62561591; called by muse, mutect2, varscan2
- GNPAT | c.1548C>T p.F516= | Silent (SNP) | VAF 17/62 reads (27%) | catalogued as rs894517069, COSV64153270; called by muse, mutect2
- GRIA2 | c.1794C>T p.L598= | Silent (SNP) | VAF 8/22 reads (36%) | catalogued as COSV52387290; called by muse, mutect2, varscan2
- GRID1 | c.693C>T p.L231= | Silent (SNP) | VAF 13/49 reads (27%) | catalogued as COSV60023036; called by muse, mutect2, varscan2
- GUCY1B1 | c.1488C>T p.I496= | Silent (SNP) | VAF 19/37 reads (51%) | catalogued as COSV52374870; called by muse, mutect2, varscan2
- GUCY2C | c.2007C>T p.I669= | Silent (SNP) | VAF 14/49 reads (29%) | catalogued as rs1196151189, COSV53788917; called by muse, mutect2, varscan2
- H2AC21 | c.60C>T p.S20= | Silent (SNP) | VAF 30/98 reads (31%) | catalogued as COSV58611766; called by muse, mutect2, varscan2
- HECW1 | c.1635G>A p.V545= | Silent (SNP) | VAF 10/24 reads (42%) | catalogued as COSV67826648; called by muse, mutect2, varscan2
- HERC2 | c.1731C>T p.R577= | Silent (SNP) | VAF 14/31 reads (45%) | catalogued as rs138275638; called by muse, mutect2, varscan2
- HGS | c.2046C>T p.L682= | Silent (SNP) | VAF 3/18 reads (17%) | catalogued as rs989063681, COSV61267407; called by muse, mutect2
- HNRNPA2B1 | c.111G>A p.L37= (on ENST00000354667 / NM_031243.3; = p.L25= on NM_002137.4) | Silent (SNP) | VAF 18/63 reads (29%) | catalogued as COSV100522850; called by muse, mutect2, varscan2
- HRH3 | c.1131G>C p.L377= | Silent (SNP) | VAF 16/69 reads (23%) | catalogued as rs1416840981, COSV58048216; called by muse, mutect2, varscan2
- HRH3 | c.135C>T p.I45= | Silent (SNP) | VAF 11/30 reads (37%) | catalogued as rs1286903760, COSV100420455; called by muse, varscan2
- HSD3B7 | c.1047G>A p.S349= | Silent (SNP) | VAF 19/75 reads (25%) | catalogued as rs746926891, COSV52680239; called by muse, mutect2, varscan2
- HYAL4 | c.966C>T p.V322= | Silent (SNP) | VAF 12/21 reads (57%) | catalogued as COSV56138243; called by muse, mutect2, varscan2
- ICAM1 | c.507C>T p.V169= | Silent (SNP) | VAF 6/33 reads (18%) | catalogued as COSV53424428; called by muse, mutect2, varscan2
- ICE1 | c.4959G>A p.L1653= | Silent (SNP) | VAF 10/22 reads (45%) | catalogued as COSV56822379; called by muse, mutect2, varscan2
- IFT172 | c.2310C>T p.I770= | Silent (SNP) | VAF 7/26 reads (27%) | catalogued as rs747166388, COSV53132184; called by muse, mutect2, varscan2
- IGHD | c.657G>A p.L219= | Silent (SNP) | VAF 20/55 reads (36%) | catalogued as rs1380708567, COSV101162806; called by muse, mutect2, varscan2
- IGHV3-20 | c.111G>A p.L37= | Silent (SNP) | VAF 27/72 reads (38%) | called by muse, mutect2, varscan2
- IL36A | c.90C>T p.L30= | Silent (SNP) | VAF 12/37 reads (32%) | catalogued as COSV52082976; called by muse, mutect2, varscan2
- IRF2BPL | c.1179G>A p.K393= | Silent (SNP) | VAF 22/52 reads (42%) | catalogued as rs1365820341, COSV53146637; called by muse, mutect2, varscan2
- KATNIP | c.2178C>T p.V726= | Silent (SNP) | VAF 6/15 reads (40%) | catalogued as COSV55178115; called by muse, mutect2, varscan2
- KHSRP | c.693G>A p.Q231= | Silent (SNP) | VAF 5/45 reads (11%) | catalogued as COSV101231137; called by muse, mutect2
- KIAA1109 | c.3129G>A p.V1043= | Silent (SNP) | VAF 10/23 reads (43%) | catalogued as COSV99145971; called by muse, mutect2, varscan2
- KIAA1755 | c.1911C>T p.D637= | Silent (SNP) | VAF 22/88 reads (25%) | catalogued as rs112826952; called by muse, mutect2
- KIF4A | c.3624G>A p.K1208= | Silent (SNP) | VAF 10/52 reads (19%) | catalogued as rs1319727058, COSV100978554; called by mutect2, varscan2
- KIF4B | c.2988C>T p.L996= | Silent (SNP) | VAF 9/29 reads (31%) | catalogued as rs372105918; called by muse, mutect2, varscan2
- KLF8 | c.615C>T p.L205= | Silent (SNP) | VAF 8/40 reads (20%) | catalogued as COSV63847602; called by muse, mutect2, varscan2
- KMT2D | c.8281C>T p.L2761= | Silent (SNP) | VAF 16/25 reads (64%) | catalogued as COSV56427994; called by muse, mutect2, varscan2
- KNG1 | c.945G>A p.K315= | Silent (SNP) | VAF 17/50 reads (34%) | catalogued as COSV53977172, COSV53977464; called by muse, mutect2, varscan2
- KREMEN1 | c.1203C>T p.I401= (on ENST00000407188; = p.I403= on NM_032045.5) | Silent (SNP) | VAF 24/64 reads (38%) | catalogued as COSV59912292; called by muse, mutect2, varscan2
- KSR1 | c.354G>A p.V118= | Silent (SNP) | VAF 11/43 reads (26%) | catalogued as rs752021766, COSV99258233; called by muse, mutect2, varscan2
- KSR2 | c.2751G>A p.E917= | Silent (SNP) | VAF 23/70 reads (33%) | catalogued as COSV100194253, COSV56665211; called by muse, mutect2, varscan2
- LAMB2 | c.2634C>T p.V878= | Silent (SNP) | VAF 6/40 reads (15%) | catalogued as COSV59732510; called by muse, mutect2, varscan2
- LAMB2 | c.2310C>T p.I770= | Silent (SNP) | VAF 11/52 reads (21%) | catalogued as COSV59732520; called by muse, mutect2, varscan2
- LAMB2 | c.1779C>T p.S593= | Silent (SNP) | VAF 4/23 reads (17%) | catalogued as COSV59732531; called by muse, mutect2
- LAMB3 | c.1899G>A p.Q633= | Silent (SNP) | VAF 13/53 reads (25%) | catalogued as COSV61916295; called by muse, mutect2, varscan2
- LAMC2 | c.2748G>A p.G916= | Silent (SNP) | VAF 9/46 reads (20%) | catalogued as COSV51454389, COSV99916867; called by muse, mutect2, varscan2
- LDHD | c.600G>A p.L200= | Silent (SNP) | VAF 8/19 reads (42%) | catalogued as COSV55580561; called by muse, mutect2, varscan2
- LIME1 | c.720C>G p.L240= | Silent (SNP) | VAF 6/41 reads (15%) | catalogued as COSV55508658, COSV99829750; called by muse, mutect2, varscan2
- LMTK2 | c.1110C>T p.L370= | Silent (SNP) | VAF 13/29 reads (45%) | catalogued as COSV51993967, COSV51997520; called by muse, mutect2, varscan2
- LRMDA | c.162C>T p.L54= | Silent (SNP) | VAF 4/14 reads (29%) | catalogued as COSV65271923; called by muse, mutect2, varscan2
- LRP2 | c.2133C>T p.L711= | Silent (SNP) | VAF 8/22 reads (36%) | catalogued as rs1333983104, COSV55548788; called by muse, mutect2, varscan2
- LRRC4B | c.1398C>T p.S466= | Silent (SNP) | VAF 13/39 reads (33%) | catalogued as rs1017785351, COSV65349699; called by muse, mutect2, varscan2
- MAB21L1 | c.198C>T p.L66= | Silent (SNP) | VAF 6/22 reads (27%) | catalogued as COSV59774989, COSV59822046; called by muse, mutect2, varscan2
- MAP2K4 | c.222G>A p.E74= | Silent (SNP) | VAF 13/30 reads (43%) | catalogued as COSV62256453; called by muse, mutect2, varscan2
- MARCHF5 | c.90G>A p.V30= | Silent (SNP) | VAF 16/41 reads (39%) | catalogued as rs770273807, COSV62769461; called by muse, mutect2, varscan2
- MBD3 | c.606G>A p.K202= | Silent (SNP) | VAF 17/52 reads (33%) | catalogued as rs778658441, COSV50083283; called by muse, mutect2, varscan2
- MEIS1 | c.133C>T p.L45= | Silent (SNP) | VAF 10/20 reads (50%) | catalogued as COSV55485434; called by muse, mutect2, varscan2
- MSC | c.363C>T p.R121= | Silent (SNP) | VAF 16/33 reads (48%) | catalogued as COSV57696190, COSV57696500; called by muse, mutect2, varscan2
- MUC5B | c.11088G>C p.L3696= | Silent (SNP) | VAF 21/29 reads (72%) | catalogued as COSV71591264; called by muse, mutect2, varscan2
- MYBPC2 | c.408C>T p.L136= | Silent (SNP) | VAF 7/40 reads (18%) | catalogued as rs775524133, COSV63094549; called by muse, mutect2, varscan2
- MYLK | c.87G>A p.L29= | Silent (SNP) | VAF 14/48 reads (29%) | catalogued as COSV100658566; called by muse, mutect2
- MYO1C | c.3054C>T p.I1018= (on ENST00000648651 / NM_001080779.2; = p.I983= on NM_033375.5) | Silent (SNP) | VAF 9/45 reads (20%) | catalogued as COSV62998951; called by muse, mutect2, varscan2
- MYO7A | c.804G>A p.K268= | Silent (SNP) | VAF 6/61 reads (10%) | catalogued as COSV101289049; called by muse, mutect2, varscan2
- NAALAD2 | c.921G>A p.K307= | Silent (SNP) | VAF 8/45 reads (18%) | catalogued as COSV58960075; called by muse, mutect2, varscan2
- NBEA | c.6462C>T p.L2154= | Silent (SNP) | VAF 4/41 reads (10%) | catalogued as COSV100077124; called by muse, mutect2, varscan2
- NLRP1 | c.2952C>T p.F984= | Silent (SNP) | VAF 9/21 reads (43%) | catalogued as COSV52563559; called by muse, mutect2, varscan2
- NSD1 | c.6897C>T p.L2299= | Silent (SNP) | VAF 11/25 reads (44%) | catalogued as rs768193868, COSV61774403; called by muse, mutect2, varscan2
- NSD2 | c.3234C>G p.V1078= | Silent (SNP) | VAF 9/44 reads (20%) | catalogued as COSV56389245; called by muse, mutect2, varscan2
- OPHN1 | c.1671C>T p.I557= | Silent (SNP) | VAF 7/43 reads (16%) | catalogued as rs754504347, COSV62781567; called by muse, mutect2, varscan2
- OPLAH | c.1653G>A p.L551= | Silent (SNP) | VAF 8/15 reads (53%) | catalogued as COSV70677725; called by muse, mutect2, varscan2
- OR10A4 | c.501C>T p.F167= | Silent (SNP) | VAF 22/55 reads (40%) | catalogued as COSV65842625; called by muse, mutect2
- OR10J5 | c.732C>T p.L244= | Silent (SNP) | VAF 19/75 reads (25%) | catalogued as rs1229925831, COSV58385709; called by muse, mutect2, varscan2
- OR10J5 | c.144C>T p.I48= | Silent (SNP) | VAF 15/59 reads (25%) | catalogued as COSV58385720, COSV58387096; called by muse, mutect2, varscan2
- OR1E1 | c.453G>A p.L151= | Silent (SNP) | VAF 24/66 reads (36%) | catalogued as COSV59458733; called by muse, mutect2, varscan2
- OR2M3 | c.12G>A p.E4= | Silent (SNP) | VAF 18/86 reads (21%) | catalogued as COSV71758976; called by muse, mutect2, varscan2
- OR4C15 | c.345C>T p.F115= (on ENST00000314644; = p.F61= on NM_001001920.2) | Silent (SNP) | VAF 33/102 reads (32%) | catalogued as COSV58952097, COSV58952612; called by muse, mutect2, varscan2
- OR4X1 | c.177C>T p.F59= | Silent (SNP) | VAF 16/48 reads (33%) | catalogued as COSV60722604; called by muse, mutect2, varscan2
- OR52N5 | c.273C>T p.L91= | Silent (SNP) | VAF 7/18 reads (39%) | catalogued as COSV57698675; called by muse, mutect2, varscan2
- OXCT2 | c.1527C>G p.L509= | Silent (SNP) | VAF 13/75 reads (17%) | catalogued as COSV59593634; called by muse, mutect2, varscan2
- PABPC3 | c.171G>A p.V57= | Silent (SNP) | VAF 23/55 reads (42%) | catalogued as COSV55799366; called by muse, mutect2, varscan2
- PALB2 | c.2883G>A p.L961= | Silent (SNP) | VAF 13/53 reads (25%) | catalogued as COSV55164160; called by muse, mutect2, varscan2
- PAPPA2 | c.93G>A p.K31= | Silent (SNP) | VAF 21/64 reads (33%) | catalogued as COSV62776206, COSV62782333; called by muse, mutect2, varscan2
- PCDH17 | c.2157C>T p.L719= | Silent (SNP) | VAF 9/28 reads (32%) | catalogued as rs1178473580, COSV64973274; called by muse, mutect2, varscan2
- PER2 | c.2973C>T p.L991= | Silent (SNP) | VAF 24/46 reads (52%) | catalogued as COSV54522768; called by muse, mutect2, varscan2
- PIK3CB | c.2646G>A p.L882= | Silent (SNP) | VAF 3/16 reads (19%) | catalogued as rs1377388133, COSV56684941; called by muse, mutect2
- PIK3CD | c.2994C>T p.L998= | Silent (SNP) | VAF 4/40 reads (10%) | catalogued as COSV63128034; called by muse, mutect2
- PLGLB2 | c.25C>T p.L9= | Silent (SNP) | VAF 7/48 reads (15%) | catalogued as COSV63948050; called by mutect2, varscan2
- PLPBP | c.39C>T p.V13= | Silent (SNP) | VAF 13/26 reads (50%) | catalogued as rs1391609258, COSV52420309; called by muse, mutect2, varscan2
- PLSCR1 | c.666G>A p.E222= | Silent (SNP) | VAF 9/46 reads (20%) | catalogued as COSV100678307; called by muse, mutect2, varscan2
- PMEL | c.7C>T p.L3= | Silent (SNP) | VAF 15/40 reads (38%) | catalogued as COSV57186391; called by muse, mutect2, varscan2
- POTEH | c.69G>A p.K23= | Silent (SNP) | VAF 42/130 reads (32%) | catalogued as rs1475171528, COSV100625302, COSV58881926; called by muse, mutect2, varscan2
- PPP2R5E | c.393C>T p.D131= | Silent (SNP) | VAF 5/14 reads (36%) | catalogued as COSV61741299; called by muse, mutect2, varscan2
- PPP4R3B | c.189G>A p.Q63= | Silent (SNP) | VAF 18/38 reads (47%) | catalogued as COSV55401209, COSV55404102; called by muse, varscan2
- PRDM2 | c.1143C>T p.I381= | Silent (SNP) | VAF 15/64 reads (23%) | catalogued as COSV52445087; called by muse, mutect2, varscan2
- PRKDC | c.11367G>A p.R3789= | Silent (SNP) | VAF 6/23 reads (26%) | catalogued as COSV58049033; called by muse, mutect2, varscan2
- PRSS55 | c.246G>A p.Q82= | Silent (SNP) | VAF 41/93 reads (44%) | catalogued as COSV100153645; called by muse, mutect2, varscan2
- PSMA3 | c.642C>T p.L214= | Silent (SNP) | VAF 24/65 reads (37%) | catalogued as COSV53616868, COSV53617896; called by muse, mutect2, varscan2
- PSMB1 | c.477G>A p.Q159= | Silent (SNP) | VAF 8/41 reads (20%) | catalogued as COSV100079807, COSV100079982; called by muse, mutect2, varscan2
- PTPRM | c.4140C>T p.G1380= | Silent (SNP) | VAF 12/67 reads (18%) | catalogued as rs376481019; called by muse, mutect2
- PTPRS | c.1536C>G p.L512= | Silent (SNP) | VAF 6/35 reads (17%) | catalogued as COSV53616295; called by muse, mutect2, varscan2
- PUSL1 | c.837C>G p.L279= | Silent (SNP) | VAF 29/114 reads (25%) | catalogued as rs1208494032, COSV60087955; called by muse, mutect2, varscan2
- RASA3 | c.1686G>A p.S562= | Silent (SNP) | VAF 12/61 reads (20%) | catalogued as rs557790275, COSV61865875; called by muse, mutect2, varscan2
- RASGRF2 | c.138C>T p.L46= | Silent (SNP) | VAF 25/63 reads (40%) | catalogued as COSV54127297; called by muse, mutect2, varscan2
- RASSF10 | c.378C>T p.F126= | Silent (SNP) | VAF 7/18 reads (39%) | called by muse, mutect2, varscan2
- RNF148 | c.474G>C p.L158= | Silent (SNP) | VAF 19/44 reads (43%) | catalogued as COSV57358070, COSV57375795; called by muse, mutect2, varscan2
- RPL14 | c.384G>A p.K128= | Silent (SNP) | VAF 16/43 reads (37%) | catalogued as rs763976711, COSV59082732; called by muse, mutect2, varscan2
- RUBCNL | c.570G>C p.S190= | Silent (SNP) | VAF 28/61 reads (46%) | catalogued as rs143042360, COSV59787208; called by muse, mutect2, varscan2
- SACM1L | c.387T>C p.D129= | Silent (SNP) | VAF 17/70 reads (24%) | catalogued as COSV66612961; called by muse, mutect2, varscan2
- SCAMP4 | c.327C>T p.F109= | Silent (SNP) | VAF 8/93 reads (9%) | catalogued as rs1451391862, COSV100290653, COSV60191862; called by muse, mutect2, varscan2
- SCD5 | c.39C>T p.F13= | Silent (SNP) | VAF 13/35 reads (37%) | catalogued as COSV51102340, COSV99262192; called by muse, mutect2, varscan2
- SCN5A | c.1866G>A p.V622= | Silent (SNP) | VAF 6/55 reads (11%) | catalogued as COSV61121051; called by muse, mutect2
- SDHB | c.207C>A p.G69= | Silent (SNP) | VAF 4/51 reads (8%) | catalogued as COSV100973324; called by muse, mutect2
- SEMA6B | c.1089G>A p.T363= | Silent (SNP) | VAF 12/52 reads (23%) | catalogued as rs370892574; called by muse, mutect2
- SEPTIN1 | c.855G>A p.G285= (on ENST00000321367; = p.G238= on NM_052838.6 and 1 other RefSeq transcript) | Silent (SNP) | VAF 25/98 reads (26%) | catalogued as COSV58441791; called by muse, mutect2, varscan2
- SEPTIN1 | c.714G>A p.L238= (on ENST00000321367; = p.L191= on NM_052838.6 and 1 other RefSeq transcript) | Silent (SNP) | VAF 6/66 reads (9%) | catalogued as COSV58442258; called by muse, mutect2
- SEPTIN6 | c.1137G>A p.K379= | Silent (SNP) | VAF 18/82 reads (22%) | catalogued as COSV59713447; called by muse, mutect2, varscan2
- SEPTIN9 | c.375C>T p.I125= (on ENST00000427177 / NM_001113491.2; = p.I107= on NM_006640.4) | Silent (SNP) | VAF 13/22 reads (59%) | catalogued as rs573465338, COSV61203709; called by muse, mutect2, varscan2
- SH3KBP1 | c.966C>T p.F322= | Silent (SNP) | VAF 15/56 reads (27%) | catalogued as rs749994475, COSV65640432; called by muse, mutect2, varscan2
- SIX3 | c.393C>T p.I131= | Silent (SNP) | VAF 9/21 reads (43%) | catalogued as COSV53226956, COSV99578415; called by muse, mutect2, varscan2
- SKIL | c.1035G>A p.K345= | Silent (SNP) | VAF 12/23 reads (52%) | catalogued as rs1286478475, COSV99378070; called by muse, mutect2, varscan2
- SLC25A6 | c.357C>T p.S119= | Silent (SNP) | VAF 20/93 reads (22%) | catalogued as rs140860839, COSV67317648; called by muse, mutect2, varscan2
- SLC34A2 | c.1497C>T p.I499= | Silent (SNP) | VAF 14/64 reads (22%) | catalogued as COSV65941214; called by muse, mutect2, varscan2
- SLC9A7 | c.348G>A p.L116= | Silent (SNP) | VAF 11/62 reads (18%) | catalogued as COSV100091542; called by muse, mutect2, varscan2
- SLCO6A1 | c.642C>T p.V214= | Silent (SNP) | VAF 5/27 reads (19%) | catalogued as COSV65808406; called by muse, mutect2, varscan2
- SLITRK4 | c.595C>T p.L199= | Silent (SNP) | VAF 9/46 reads (20%) | catalogued as COSV62023171; called by muse, mutect2, varscan2
- SLITRK5 | c.2652C>T p.P884= | Silent (SNP) | VAF 23/59 reads (39%) | catalogued as COSV61522082; called by muse, mutect2, varscan2
- SNTB1 | c.417C>T p.I139= | Silent (SNP) | VAF 17/43 reads (40%) | catalogued as rs773014097, COSV101179790; called by muse, mutect2, varscan2
60 further variants in this file (0 protein-altering or splice-affecting, 46 silent, 14 other) are not listed here.
